Somatic mutation profile of tumor specimen TCGA-F1-6177-01A (aliquot TCGA-F1-6177-01A-11D-1800-08) from TCGA case TCGA-F1-6177, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-F1-6177-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9da3f1e4-9c6e-4636-9d0e-d2315987da28.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F1-6177-10A (Blood Derived Normal), aliquot TCGA-F1-6177-10A-01D-1800-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3776a85e-da95-4ecb-aa5e-0b32d52bd2ad

The open-access MAF lists 1,534 somatic variants for this specimen: 1,165 protein-altering or splice-affecting, 338 silent, 31 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 756, Silent 338, Frame Shift Del 266, Frame Shift Ins 74, Nonsense Mutation 41, Intron 12, Splice Region 12, Splice Site 9, RNA 9, In Frame Del 6, 3'UTR 4, 5'UTR 2.

Variants (750 of 1,534; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHI1 | c.910dup p.T304Nfs*6 | Frame Shift Ins (INS) | VAF 19/40 reads (48%) | catalogued as rs753874898; ClinVar: pathogenic; called by mutect2, varscan2
- ALDH18A1 | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs863225045, CM159182, CM159183, COSV64662951; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATP2A1 | c.2464dup p.R822Pfs*39 | Frame Shift Ins (INS) | VAF 28/83 reads (34%) | catalogued as rs751365374; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BLM | c.1544del p.N515Mfs*16 | Frame Shift Del (DEL) | VAF 30/86 reads (35%) | catalogued as rs367543043; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CFTR | c.3197G>A p.R1066H | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs121909019, CM152190, CM920174, CM930127, COSV50069159; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTCF | c.610dup p.T204Nfs*26 | Frame Shift Ins (INS) | VAF 26/63 reads (41%) | catalogued as rs886041997; ClinVar: pathogenic; called by mutect2, varscan2
- DNAAF3 | c.997del p.D333Tfs*75 (on ENST00000524407 / NM_001256715.2; = p.D380Tfs*75 on NM_178837.4) | Frame Shift Del (DEL) | VAF 44/142 reads (31%) | catalogued as rs756430359; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- ECM1 | c.157C>T p.R53* | Nonsense Mutation (SNP) | VAF 35/127 reads (28%) | catalogued as rs121909115, CM031960; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FLG | c.477del p.E160Kfs*34 | Frame Shift Del (DEL) | VAF 42/101 reads (42%) | catalogued as rs746683647; ClinVar: pathogenic; called by mutect2, varscan2
- GCK | c.571C>T p.R191W | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1085307455, CM001170, COSV60785720; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HSPG2 | c.1219del p.Q407Rfs*3 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | catalogued as rs763945561; ClinVar: likely pathogenic; called by mutect2, varscan2
- KANSL1 | c.2899del p.Q967Sfs*46 (on ENST00000574590 / NM_001193465.2; = p.Q968Sfs*46 on NM_015443.4) | Frame Shift Del (DEL) | VAF 27/67 reads (40%) | catalogued as rs1374665357; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- KMT2B | c.521dup p.T176Dfs*8 | Frame Shift Ins (INS) | VAF 26/62 reads (42%) | catalogued as rs763183959; ClinVar: pathogenic; called by mutect2, varscan2
- LRP2 | c.13139dup p.C4381Mfs*12 | Frame Shift Ins (INS) | VAF 16/40 reads (40%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 71/181 reads (39%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- MSH6 | c.3261del p.F1088Sfs*2 | Frame Shift Del (DEL) | VAF 25/70 reads (36%) | hotspot (GDC flag); catalogued as rs267608078, COSV99029757; ClinVar: pathogenic; called by mutect2, varscan2
- MYH11 | c.5787-4707del | Intron (DEL) | VAF 9/18 reads (50%) | catalogued as rs747392139, COSV100257523; ClinVar: uncertain significance / benign / likely benign / likely pathogenic; called by mutect2, varscan2
- NF1 | c.2033del p.P678Rfs*10 | Frame Shift Del (DEL) | VAF 7/62 reads (11%) | catalogued as rs587781807, CX1511110; ClinVar: pathogenic; called by pindel, varscan2*
- NIPBL | c.1808del p.K603Sfs*11 | Frame Shift Del (DEL) | VAF 25/73 reads (34%) | catalogued as rs727503767; ClinVar: pathogenic; called by mutect2, varscan2
- OCA2 | c.2359G>A p.A787T | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs142988897, CM068052; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 51/119 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs1064793663, COSV55877982, COSV55886419, COSV56022812; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1638G>T p.Q546H | Missense Mutation (SNP) | VAF 29/61 reads (48%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as rs1057519940, COSV55883555, COSV55928679, COSV55957396; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PLEC | c.6490C>T p.R2164* (on ENST00000322810 / NM_201380.4; = p.R2054* on NM_000445.5) | Nonsense Mutation (SNP) | VAF 9/12 reads (75%) | catalogued as rs368550010; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RIN2 | c.1878dup p.I627Hfs*7 (on ENST00000255006 / NM_001242581.1; = p.I578Hfs*7 on NM_018993.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 6/14 reads (43%) | catalogued as rs759390822; ClinVar: pathogenic; called by mutect2, varscan2
- SETX | c.23C>T p.T8M | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057520367, COSV56388948; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TPP1 | c.1449del p.I484Sfs*4 | Frame Shift Del (DEL) | VAF 76/195 reads (39%) | catalogued as rs1057516264; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- TUBB4A | c.763G>A p.V255I | Missense Mutation (SNP) | VAF 56/116 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.328); catalogued as rs767399782, CM148654, COSV51158580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- A1CF | c.1430A>G p.Q477R (on ENST00000373993 / NM_138932.2; = p.Q469R on NM_014576.4) | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.165); catalogued as COSV50980850; called by muse, mutect2, varscan2
- AACS | c.1598del p.G533Afs*51 | Frame Shift Del (DEL) | VAF 13/32 reads (41%) | catalogued as rs1326010455; called by mutect2, pindel, varscan2
- AADAC | c.631A>G p.K211E | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV51760160; called by muse, mutect2, varscan2
- ABCC5 | c.3269del p.L1090Cfs*26 | Frame Shift Del (DEL) | VAF 9/26 reads (35%) | catalogued as rs749943218; called by mutect2, varscan2
- ABCC8 | c.913T>C p.F305L | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT tolerated (0.53); PolyPhen benign (0.041); catalogued as COSV56853364; called by muse, mutect2, varscan2
- ABCG4 | c.1711G>A p.V571I | Missense Mutation (SNP) | VAF 81/170 reads (48%) | SIFT tolerated (0.3); PolyPhen benign (0.065); catalogued as COSV56644456; called by muse, mutect2, varscan2
- ABLIM2 | c.354del p.D120Tfs*3 | Frame Shift Del (DEL) | VAF 8/23 reads (35%) | catalogued as rs749606695; called by mutect2, pindel, varscan2
- AC092718.8 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.17); catalogued as COSV59601898; called by muse, mutect2, varscan2
- ACAN | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 64/140 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs760009352, COSV61363972; called by muse, mutect2, varscan2
- ACIN1 | c.3478C>T p.R1160* | Nonsense Mutation (SNP) | VAF 37/76 reads (49%) | catalogued as COSV52978292; called by muse, varscan2
- ACIN1 | c.3418C>T p.R1140W | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); catalogued as rs545679768, COSV52978318; called by muse, varscan2
- ACTR10 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs199506195, COSV54299107; called by muse, varscan2
- ACVR1B | c.1211A>G p.Y404C | Missense Mutation (SNP) | VAF 94/111 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57778294; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 14/123 reads (11%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAMTS1 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as rs1379843029, COSV53171520; called by muse, varscan2
- ADCY3 | c.2638C>T p.R880C | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs369517755; called by muse, mutect2, varscan2
- ADD3 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as rs770245298, COSV53321061, COSV99523315; called by muse, mutect2, varscan2
- ADGRF4 | c.1298C>T p.T433M | Missense Mutation (SNP) | VAF 73/163 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs146828294, COSV51951121; called by muse, mutect2, varscan2
- ADGRV1 | c.7655C>T p.A2552V | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.109); catalogued as COSV67989459; called by muse, mutect2, varscan2
- ADIPOR2 | c.839G>A p.G280E | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs780258481, COSV63946991; called by muse, mutect2, varscan2
- ADRA1D | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.42); catalogued as rs1305160550; called by muse, mutect2
- ADRB1 | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.71); PolyPhen benign (0.197); catalogued as COSV65168102; called by muse, mutect2, varscan2
- AFAP1 | c.1235T>C p.L412P | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as COSV61796802; called by muse, mutect2, varscan2
- AGMAT | c.550G>A p.V184M | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs764996093, COSV65436011; called by muse, mutect2, varscan2
- AGTPBP1 | c.1409G>A p.G470D (on ENST00000357081 / NM_001330701.2; = p.G430D on NM_015239.2) | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.65); PolyPhen benign (0.039); catalogued as COSV61274062; called by muse, mutect2, varscan2
- AKAP13 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV63452348; called by muse, mutect2, varscan2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 24/61 reads (39%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- AKAP8L | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs981255922, COSV68473884; called by muse, mutect2
- AKAP9 | c.9208C>T p.R3070W (on ENST00000359028; = p.R3046W on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 214/355 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs780099038, COSV62340743; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AKR7A3 | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.094); catalogued as COSV64389395; called by muse, mutect2, varscan2
- AKT3 | c.1256T>C p.V419A | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV55612739; called by muse, mutect2, varscan2
- AL441992.2 | c.812T>G p.L271R | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV56915122; called by muse, mutect2, varscan2
- ALAS1 | c.182C>A p.T61N | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV59626746, COSV59628549; called by muse, mutect2, varscan2
- ALDH1A3 | c.1061G>T p.G354V | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60902407; called by muse, mutect2
- ALDOC | c.785C>A p.P262H | Missense Mutation (SNP) | VAF 81/184 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52025364; called by muse, mutect2, varscan2
- ALMS1 | c.761T>C p.L254P | Missense Mutation (SNP) | VAF 68/176 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52514125, COSV52523404; called by muse, mutect2, varscan2
- ALPK1 | c.1121C>T p.T374M | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs772519624, COSV51586169; called by muse, mutect2, varscan2
- ALPL | c.1130C>T p.A377V | Missense Mutation (SNP) | VAF 49/144 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756418235, HM971625, COSV66376066; called by muse, mutect2, varscan2
- AMHR2 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 51/59 reads (86%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs748586967, COSV57686254; called by muse, varscan2
- ANGPT2 | c.389A>T p.N130I | Missense Mutation (SNP) | VAF 28/44 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV57338224; called by muse, mutect2, varscan2
- ANK2 | c.1835C>T p.A612V | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); catalogued as COSV52172070; called by muse, mutect2, varscan2
- ANKIB1 | c.437del p.N146Tfs*12 | Frame Shift Del (DEL) | VAF 20/66 reads (30%) | catalogued as rs201434379; called by mutect2, varscan2
- ANKS6 | c.596T>C p.I199T | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated (0.61); PolyPhen benign (0.031); catalogued as rs767450669, COSV62050985; called by muse, mutect2, varscan2
- ANO3 | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 54/124 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.037); catalogued as rs766239304, COSV56793786; called by muse, mutect2, varscan2
- AP1G2 | c.1290G>A p.A430= | Splice Region (SNP) | VAF 12/33 reads (36%) | catalogued as rs373872679; called by muse, mutect2, varscan2
- AP3B2 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55607240; called by muse, mutect2, varscan2
- APBA2 | c.1556C>T p.A519V | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs746149119, COSV67105171; called by muse, mutect2, varscan2
- AREL1 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.074); catalogued as COSV62667054; called by muse, mutect2, varscan2
- ARFGEF2 | c.4003G>A p.E1335K | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as rs374632843; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGAP22 | c.448G>A p.G150R | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs369200749, COSV50932711; called by muse, mutect2, varscan2
- ARHGAP31 | c.1267G>A p.A423T | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0.062); catalogued as COSV51795692; called by muse, mutect2, varscan2
- ARHGAP33 | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs373692589, COSV50131638; called by muse, mutect2, varscan2
- ARHGEF10L | c.2852G>A p.R951Q | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.517); catalogued as rs542988034, COSV51435757; called by muse, mutect2, varscan2
- ARHGEF40 | c.2819G>A p.R940H | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs1260057829, COSV53881875; called by muse, mutect2, varscan2
- ARID5B | c.3026C>G p.A1009G | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as COSV54415348; called by muse, mutect2, varscan2
- ARRDC3 | c.407A>G p.Y136C | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54365763; called by muse, mutect2, varscan2
- ASXL1 | c.1634G>A p.R545H | Missense Mutation (SNP) | VAF 58/141 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); catalogued as rs149449801, COSV60123826; called by muse, mutect2, varscan2
- ATAD3A | c.206-1G>T p.X69_splice | Splice Site (SNP) | VAF 10/30 reads (33%) | catalogued as COSV59234429; called by muse, mutect2
- ATAT1 | c.584G>A p.R195Q | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.616); catalogued as rs1324169608, COSV57348048; called by muse, mutect2, varscan2
- ATIC | c.1679C>T p.A560V | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs372018177; called by muse, mutect2, varscan2
- ATP10A | c.2642C>T p.A881V | Missense Mutation (SNP) | VAF 53/106 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs142704035, COSV63514865; called by muse, mutect2, varscan2
- ATP11A | c.1847T>C p.L616P | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV52116153, COSV99369235; called by muse, mutect2, varscan2
- ATP1A2 | c.1820G>A p.G607D | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63404631; called by muse, mutect2, varscan2
- ATP6V1C2 | c.32G>T p.G11V | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV55362079; called by muse, mutect2, varscan2
- ATP8B1 | c.2373del p.P792Hfs*8 | Frame Shift Del (DEL) | VAF 36/90 reads (40%) | catalogued as rs1568184131, COSV99377078; called by mutect2, pindel, varscan2
- ATP8B3 | c.2023del p.A675Qfs*97 | Frame Shift Del (DEL) | VAF 30/91 reads (33%) | catalogued as rs750175510; called by mutect2, pindel, varscan2
- ATP9B | c.3403C>T p.R1135C | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs768778637, COSV56947903; called by muse, mutect2, varscan2
- ATXN7 | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.083); catalogued as rs759418780, COSV55752836; called by muse, mutect2, varscan2
- AXIN1 | c.1523del p.G508Vfs*197 | Frame Shift Del (DEL) | VAF 7/15 reads (47%) | catalogued as rs760961378; called by mutect2, pindel, varscan2
- AXIN1 | c.792del p.G265Efs*149 | Frame Shift Del (DEL) | VAF 35/118 reads (30%) | catalogued as COSV51989295; called by mutect2, pindel, varscan2
- AXIN1 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51988758; called by muse, mutect2, varscan2
- B3GALT4 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV65851885; called by muse, mutect2, varscan2
- B3GAT1 | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.719); catalogued as rs749052528, COSV56995458; called by muse, mutect2, varscan2
- B4GALNT2 | c.887C>T p.A296V | Missense Mutation (SNP) | VAF 31/214 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.382); catalogued as COSV55927157; called by muse, mutect2, varscan2
- BAIAP2L2 | c.1116C>T p.S372= | Splice Region (SNP) | VAF 8/22 reads (36%) | catalogued as rs1444234132, COSV67732925; called by muse, mutect2, varscan2
- BCL7C | c.145G>A p.V49M | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53063923; called by muse, mutect2, varscan2
- BCL9 | c.3218C>T p.P1073L | Missense Mutation (SNP) | VAF 78/222 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs139858510; called by muse, mutect2, varscan2
- BDKRB1 | c.1000A>C p.S334R | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV99387828; called by muse, mutect2
- BIVM-ERCC5 | c.310A>T p.N104Y | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); catalogued as COSV57280866; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.2243-2A>C p.X748_splice | Splice Site (SNP) | VAF 73/163 reads (45%) | catalogued as COSV63245783; called by muse, mutect2, varscan2
- BLM | c.4018C>A p.P1340T | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as COSV61925270, COSV61925281; called by muse, mutect2, varscan2
- BLOC1S1 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.076); catalogued as rs771492578; called by muse, mutect2, varscan2
- BMP1 | c.2437G>A p.A813T | Missense Mutation (SNP) | VAF 45/57 reads (79%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as rs780689541, COSV60531276; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMP3 | c.957G>T p.K319N | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.551); catalogued as COSV51088892; called by muse, mutect2, varscan2
- BMP4 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV55415439; called by muse, mutect2, varscan2
- BMPR1B | c.1126C>T p.R376C | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768328319, COSV52777810, COSV99215518; called by muse, mutect2, varscan2
- BRD9 | c.946C>T p.R316W | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs763145611, COSV60246510; called by muse, mutect2, varscan2
- BRWD1 | c.5446dup p.T1816Nfs*6 | Frame Shift Ins (INS) | VAF 64/154 reads (42%) | catalogued as rs1568856013; called by mutect2, varscan2
- BSCL2 | c.757A>G p.S253G | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.97); catalogued as COSV54016498; called by muse, mutect2, varscan2
- BSN | c.8956C>T p.R2986C | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762365279, COSV56522089; called by muse, mutect2, varscan2
- BTBD9 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 81/167 reads (49%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.635); catalogued as COSV58430458; called by muse, mutect2, varscan2
- C10orf90 | c.449del p.P150Qfs*58 | Frame Shift Del (DEL) | VAF 26/65 reads (40%) | catalogued as rs762432781; called by mutect2, pindel, varscan2
- C12orf40 | c.18del p.S7Pfs*6 | Frame Shift Del (DEL) | VAF 9/28 reads (32%) | catalogued as COSV61129099; called by mutect2, pindel, varscan2
- C18orf54 | c.1102C>T p.R368W | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as rs544918205, COSV55618608; called by muse, mutect2, varscan2
- C1orf109 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.439); catalogued as rs1395872719, COSV63656954; called by muse, mutect2, varscan2
- C3orf33 | c.728dup p.L243Ffs*17 (on ENST00000340171 / NM_001308229.2; = p.L200Ffs*17 on NM_173657.2) | Frame Shift Ins (INS) | VAF 15/45 reads (33%) | catalogued as rs776314192; called by mutect2, pindel, varscan2
- C4orf17 | c.253del p.S85Pfs*10 | Frame Shift Del (DEL) | VAF 31/101 reads (31%) | catalogued as rs201447915; called by mutect2, pindel, varscan2
- CA2 | c.440del p.L147* | Frame Shift Del (DEL) | VAF 49/201 reads (24%) | catalogued as rs763603775; called by mutect2, pindel, varscan2
- CACHD1 | c.3280G>A p.A1094T | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.972); catalogued as rs753954534, COSV51553557; called by muse, mutect2, varscan2
- CACNA1G | c.4501G>A p.V1501M | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1231515784, COSV61740420; called by muse, mutect2, varscan2
- CACNG5 | c.719G>A p.G240D | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.329); catalogued as rs1165138711, COSV50056918; called by muse, mutect2
- CACTIN | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.96); catalogued as rs377058963, COSV50267861; called by muse, mutect2, varscan2
- CAMSAP2 | c.3789del p.K1263Nfs*19 (on ENST00000236925 / NM_001297707.2; = p.K1252Nfs*19 on NM_203459.3) | Frame Shift Del (DEL) | VAF 34/85 reads (40%) | catalogued as rs770273913; called by mutect2, varscan2
- CAMTA1 | c.4002G>T p.Q1334H | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.556); catalogued as COSV57886741; called by muse, mutect2, varscan2
- CAMTA2 | c.943C>T p.R315* | Nonsense Mutation (SNP) | VAF 11/37 reads (30%) | catalogued as COSV61835996; called by muse, mutect2, varscan2
- CAPN1 | c.1283G>A p.R428H | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs1423509575, COSV54199878; called by muse, mutect2, varscan2
- CARM1 | c.561C>T p.I187= | Splice Region (SNP) | VAF 101/269 reads (38%) | catalogued as rs867938978, COSV59001393; called by muse, mutect2, varscan2
- CARMIL1 | c.3006G>A p.A1002= | Splice Region (SNP) | VAF 7/13 reads (54%) | catalogued as rs368235973, COSV61518090; called by muse, mutect2, varscan2
- CASD1 | c.1626del p.A543Qfs*13 | Frame Shift Del (DEL) | VAF 18/68 reads (26%) | catalogued as rs770159446; called by mutect2, varscan2
- CASKIN2 | c.2182dup p.Q728Pfs*14 | Frame Shift Ins (INS) | VAF 14/42 reads (33%) | catalogued as rs751998890; called by mutect2, varscan2
- CASQ2 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749547712, CM067984, COSV54771908; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CASZ1 | c.2083C>T p.R695W | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1339287047, COSV59738191; called by muse, mutect2, varscan2
- CATSPERB | c.3181G>A p.A1061T | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV56429694; called by muse, mutect2, varscan2
- CBARP | c.1108del p.D370Mfs*37 (on ENST00000382477; = p.D350Mfs*40 on NM_152769.3) | Frame Shift Del (DEL) | VAF 21/61 reads (34%) | catalogued as COSV99289301; called by mutect2, pindel, varscan2
- CBLL1 | c.419del p.K140Rfs*52 | Frame Shift Del (DEL) | VAF 99/224 reads (44%) | catalogued as rs1256378164; called by mutect2, pindel, varscan2
- CCDC121 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 96/261 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53113298; called by muse, mutect2, varscan2
- CCDC141 | c.2171G>A p.R724Q | Missense Mutation (SNP) | VAF 100/206 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1429178522, COSV55373924; called by muse, mutect2, varscan2
- CCDC181 | c.1265del p.K422Sfs*6 (on ENST00000367806 / NM_001300969.1; = p.K421Sfs*6 on NM_021179.2) | Frame Shift Del (DEL) | VAF 24/52 reads (46%) | catalogued as rs759258977; called by mutect2, varscan2
- CCDC27 | c.1321G>T p.G441* | Nonsense Mutation (SNP) | VAF 44/110 reads (40%) | catalogued as COSV53901544; called by muse, mutect2, varscan2
- CCDC28A | c.80del p.N27Mfs*5 | Frame Shift Del (DEL) | VAF 14/98 reads (14%) | catalogued as rs756347761; called by mutect2, varscan2
- CCDC73 | c.1341del p.E448Kfs*5 | Frame Shift Del (DEL) | VAF 18/54 reads (33%) | catalogued as rs747079826; called by mutect2, varscan2
- CCDC80 | c.1658del p.K553Rfs*2 | Frame Shift Del (DEL) | VAF 16/36 reads (44%) | catalogued as rs1253078189; called by mutect2, varscan2
- CCDC86 | c.404C>A p.A135D | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57125629; called by muse, mutect2, varscan2
- CCL2 | c.104G>A p.C35Y | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56773704; called by muse, mutect2, varscan2
- CCN6 | c.68G>A p.G23D | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1562595135, COSV57889740; called by muse, mutect2, varscan2
- CD40LG | c.498A>C p.Q166H | Missense Mutation (SNP) | VAF 190/219 reads (87%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.544); catalogued as COSV65698740; called by muse, mutect2, varscan2
- CD6 | c.1900C>T p.P634S | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as COSV57840447; called by muse, mutect2, varscan2
- CDC14A | c.375del p.Y126Ifs*64 | Frame Shift Del (DEL) | VAF 19/87 reads (22%) | catalogued as rs773911500; called by mutect2, pindel, varscan2
- CDC20 | c.1334G>A p.R445Q | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60522439; called by muse, mutect2, varscan2
- CDH17 | c.395A>G p.E132G | Missense Mutation (SNP) | VAF 51/172 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.124); catalogued as COSV50332116; called by muse, mutect2, varscan2
- CDH24 | c.2135del p.P712Rfs*129 | Frame Shift Del (DEL) | VAF 30/77 reads (39%) | catalogued as rs752398646; called by mutect2, pindel, varscan2
- CDH9 | c.1865G>A p.C622Y | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV50329106; called by muse, mutect2, varscan2
- CDHR1 | c.1985del p.G662Afs*30 | Frame Shift Del (DEL) | VAF 51/170 reads (30%) | catalogued as COSV60560207; called by mutect2, pindel, varscan2
- CDHR1 | c.2212C>T p.R738W | Missense Mutation (SNP) | VAF 51/100 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs781596488, COSV60564119; called by muse, mutect2, varscan2
- CDHR5 | c.404A>T p.E135V | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1278287080, COSV51564620; called by muse, mutect2, varscan2
- CELSR1 | c.2653G>A p.A885T | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as COSV53093993; called by muse, mutect2, varscan2
- CELSR3 | c.6504G>T p.Q2168H | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV50886002; called by muse, mutect2, varscan2
- CELSR3 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 58/128 reads (45%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV50842252; called by muse, mutect2, varscan2
- CEMIP2 | c.3187T>C p.F1063L | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV65484690; called by muse, mutect2, varscan2
- CENPC | c.1985C>A p.T662K | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.086); catalogued as COSV56624569; called by muse, varscan2
- CENPC | c.616del p.R206Gfs*2 | Frame Shift Del (DEL) | VAF 30/66 reads (45%) | catalogued as rs1325731082; called by mutect2, varscan2
- CENPC | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as rs369384820, COSV56620938; called by muse, mutect2, varscan2
- CENPT | c.1298C>T p.A433V | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.023); catalogued as rs757492265, COSV54650773; called by muse, mutect2, varscan2
- CEP131 | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.508); catalogued as rs939917788, COSV53953475, COSV53954246; called by muse, mutect2, varscan2
- CEP290 | c.4294G>A p.A1432T | Missense Mutation (SNP) | VAF 9/9 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs747949998, COSV58353424; called by muse, mutect2, varscan2
- CFAP91 | c.501-2A>G p.X167_splice | Splice Site (SNP) | VAF 64/187 reads (34%) | catalogued as COSV56342352; called by muse, mutect2, varscan2
- CFP | c.763C>A p.P255T | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as COSV55950703; called by muse, mutect2
- CHAF1A | c.491T>C p.I164T | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV56674123; called by muse, mutect2, varscan2
- CHD5 | c.3206G>A p.R1069Q | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52419149; called by muse, mutect2, varscan2
- CHRDL1 | c.676C>T p.R226W (on ENST00000372045; = p.R232W on NM_145234.4) | Missense Mutation (SNP) | VAF 61/70 reads (87%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs765757313, COSV54326628; called by muse, mutect2, varscan2
- CHRM3 | c.1700dup p.R568Efs*26 | Frame Shift Ins (INS) | VAF 24/64 reads (38%) | catalogued as rs751548647; called by mutect2, varscan2
- CHRNB4 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1404927086, COSV55716849; called by muse, mutect2, varscan2
- CHRNE | c.904C>T p.P302S | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs979787967, COSV53418795; called by muse, mutect2
- CHST5 | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.51); PolyPhen benign (0.289); catalogued as rs369152538; called by muse, mutect2, varscan2
- CILP2 | c.2327G>A p.R776H | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs749798472, COSV52272877; called by muse, mutect2, varscan2
- CLASP2 | c.2896del p.M966Wfs*33 (on ENST00000359576; = p.M965Wfs*33 on NM_015097.3 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 40/115 reads (35%) | catalogued as rs761731080; called by mutect2, varscan2
- CLDN14 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as rs1476462549, COSV59775560; called by muse, varscan2
- CLDN9 | c.379C>T p.L127F | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as COSV60911160; called by muse, mutect2, varscan2
- CLIP1 | c.4303G>A p.D1435N (on ENST00000620786 / NM_001247997.1; = p.D1424N on NM_002956.2) | Missense Mutation (SNP) | VAF 82/97 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766712693, COSV56804603; called by muse, mutect2, varscan2
- CLK3 | c.560G>A p.R187Q (on ENST00000395066 / NM_001130028.1; = p.R39Q on NM_003992.4) | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as rs150279637; called by muse, mutect2, varscan2
- CMIP | c.688G>A p.A230T (on ENST00000537098 / NM_198390.2; = p.A136T on NM_030629.3) | Missense Mutation (SNP) | VAF 137/302 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); catalogued as rs1381906760, COSV67699213; called by muse, mutect2, varscan2
- CNKSR1 | c.1667C>T p.T556I (on ENST00000374253 / NM_001297647.2; = p.T549I on NM_006314.3) | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.69); catalogued as rs939809641, COSV58793764; called by muse, mutect2, varscan2
- CNR1 | c.1406C>T p.A469V | Missense Mutation (SNP) | VAF 94/250 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.291); catalogued as COSV62989140; called by muse, varscan2
- CNTLN | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as rs528248591, COSV52085627; called by muse, mutect2, varscan2
- CNTN6 | c.1253del p.K418Sfs*63 | Frame Shift Del (DEL) | VAF 46/58 reads (79%) | catalogued as rs758676375; called by mutect2, varscan2
- CNTNAP2 | c.253C>T p.L85F | Missense Mutation (SNP) | VAF 59/102 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV62147972; called by muse, mutect2, varscan2
- COL12A1 | c.4763C>A p.P1588H | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.907); catalogued as COSV59400042; called by muse, mutect2, varscan2
- COL12A1 | c.3796G>A p.V1266M | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59400051; called by muse, mutect2, varscan2
- COL14A1 | c.4054A>T p.I1352F | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV52854038; called by muse, mutect2
- COL1A1 | c.4248G>A p.T1416= | Splice Region (SNP) | VAF 21/48 reads (44%) | catalogued as rs746565111, COSV56806963; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL2A1 | c.1364C>T p.T455M | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.521); catalogued as rs775754967, CM160195, COSV61528195; called by muse, mutect2, varscan2
- COL9A1 | c.884G>A p.R295Q | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs943024642, COSV100294562, COSV57887401; called by muse, mutect2
- COLGALT1 | c.769C>A p.P257T | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.097); catalogued as COSV53110158; called by muse, mutect2, varscan2
- COMMD5 | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs757392773, COSV57384411; called by muse, mutect2, varscan2
- COPS2 | c.298C>T p.R100W | Missense Mutation (SNP) | VAF 57/147 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as rs745372669, COSV54644537, COSV54646082; called by muse, mutect2, varscan2
- CORIN | c.2725C>T p.R909W | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.352); catalogued as rs182487045, COSV56694512; called by muse, mutect2, varscan2
- COX4I1 | c.340A>G p.T114A | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as COSV53666220; called by muse, mutect2, varscan2
- CPA5 | c.1121T>G p.L374R | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV62570090; called by muse, mutect2, varscan2
- CRABP2 | c.58C>T p.L20F | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63959012; called by muse, mutect2, varscan2
- CRISPLD1 | c.1292G>A p.R431H | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs761680563, COSV51550546; called by muse, mutect2, varscan2
- CSMD2 | c.9470G>A p.R3157H | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs753503294, COSV53881918; called by muse, mutect2, varscan2
- CSMD3 | c.10920del p.F3640Lfs*61 (on ENST00000297405 / NM_001363185.1; = p.F3471Lfs*61 on NM_052900.3) | Frame Shift Del (DEL) | VAF 15/82 reads (18%) | catalogued as rs766438669; called by mutect2, pindel, varscan2
- CSPP1 | c.3367G>A p.V1123I (on ENST00000676605; = p.V1082I on NM_024790.6) | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.047); catalogued as rs778723931, COSV51587620, COSV99140326; called by muse, mutect2, varscan2
- CTHRC1 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 49/193 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs373203731; called by muse, mutect2, varscan2
- CTIF | c.809A>G p.N270S | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.324); catalogued as rs769967502, COSV56486948; called by muse, mutect2, varscan2
- CTTNBP2 | c.1932del p.G645Dfs*2 | Frame Shift Del (DEL) | VAF 55/108 reads (51%) | catalogued as COSV50406576; called by mutect2, pindel, varscan2
- CWF19L2 | c.1946G>A p.R649H | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs774777965, COSV56515466; called by muse, mutect2, varscan2
- CYP26A1 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV56417843; called by muse, mutect2
- CYP2B6 | c.406G>A p.G136R | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774036855, COSV100137278, COSV57844686; called by muse, mutect2, varscan2
- CYP2D6 | c.952C>A p.L318I | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as COSV62244594; called by muse, mutect2, varscan2
- DAB2IP | c.3073dup p.H1025Pfs*4 (on ENST00000408936; = p.H997Pfs*4 on NM_032552.3) | Frame Shift Ins (INS) | VAF 12/20 reads (60%) | catalogued as rs751187768; called by mutect2, varscan2
- DAO | c.835C>T p.R279* | Nonsense Mutation (SNP) | VAF 28/34 reads (82%) | catalogued as rs745766982, COSV57323331; called by muse, mutect2, varscan2
- DCAF4L2 | c.295T>C p.Y99H | Missense Mutation (SNP) | VAF 43/183 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as rs1437795180, COSV60480094; called by muse, mutect2, varscan2
- DCDC1 | c.4591C>A p.L1531I (on ENST00000597505 / NM_001367979.1; = p.L638I on NM_020869.3) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.013); catalogued as COSV58001086; called by muse, mutect2, varscan2
- DCLK2 | c.893C>A p.S298Y | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.332); catalogued as COSV56207176; called by muse, mutect2, varscan2
- DCT | c.555del p.F185Lfs*14 | Frame Shift Del (DEL) | VAF 64/144 reads (44%) | catalogued as rs762895555; called by mutect2, pindel, varscan2
- DCT | c.92C>T p.T31M | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375600704; called by muse, mutect2, varscan2
- DDX39B | c.736-3del | Splice Region (DEL) | VAF 11/29 reads (38%) | catalogued as rs755280697; called by mutect2, pindel, varscan2
- DENND1C | c.491del p.P164Lfs*29 | Frame Shift Del (DEL) | VAF 19/39 reads (49%) | catalogued as rs553532837; called by mutect2, varscan2
- DEPDC1B | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 113/329 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.259); catalogued as rs747550036, COSV54011229, COSV99409896; called by muse, mutect2, varscan2
- DHODH | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.59); catalogued as rs201823503; called by muse, mutect2, varscan2
- DHX38 | c.35G>A p.R12Q | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.885); catalogued as rs201334464, COSV51699124; called by muse, mutect2, varscan2
- DHX38 | c.1259G>A p.R420H | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.16); catalogued as rs775691753, COSV51699134; called by muse, mutect2, varscan2
- DHX8 | c.3337C>T p.R1113C | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV52254621; called by muse, mutect2
- DIDO1 | c.6101del p.P2034Rfs*240 | Frame Shift Del (DEL) | VAF 26/71 reads (37%) | catalogued as COSV56634983; called by mutect2, pindel, varscan2
- DLAT | c.716A>G p.E239G | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.255); catalogued as COSV54771743; called by muse, mutect2, varscan2
- DLG1 | c.1294A>G p.S432G | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV58386312; called by muse, mutect2
- DLG2 | c.1390G>T p.G464* | Nonsense Mutation (SNP) | VAF 38/97 reads (39%) | catalogued as COSV54662150; called by muse, mutect2, varscan2
- DMAP1 | c.1231G>A p.A411T | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.66); PolyPhen benign (0.018); catalogued as COSV60001160; called by muse, mutect2, varscan2
- DMWD | c.1417G>A p.A473T | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs759747786, COSV52179787; called by muse, mutect2
- DMXL1 | c.4838G>A p.R1613Q | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs375881972; called by muse, mutect2, varscan2
- DNA2 | c.2335del p.S779Hfs*6 | Frame Shift Del (DEL) | VAF 13/36 reads (36%) | catalogued as rs745893364; called by mutect2, varscan2
- DNAH10 | c.11150C>G p.A3717G (on ENST00000409039; = p.A3656G on NM_207437.3) | Missense Mutation (SNP) | VAF 25/28 reads (89%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs938155757; called by muse, mutect2, varscan2
- DNAH3 | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs200178510, COSV54533114; called by muse, mutect2, varscan2
- DNAH8 | c.1906T>A p.L636M | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as COSV59461318; called by muse, mutect2, varscan2
- DNAI3 | c.277del p.I93Lfs*37 | Frame Shift Del (DEL) | VAF 40/116 reads (34%) | catalogued as rs1392238080; called by mutect2, pindel, varscan2
- DNAJA1 | c.409T>C p.C137R | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58310837; called by muse, mutect2
- DNAJB11 | c.890C>T p.A297V | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.426); catalogued as rs139219315; called by muse, mutect2, varscan2
- DNASE1L2 | c.655G>A p.A219T | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.102); catalogued as rs1354402244, COSV57038417; called by muse, mutect2, varscan2
- DNMT3A | c.75C>T p.D25= | Splice Region (SNP) | VAF 10/28 reads (36%) | catalogued as rs538820253, COSV53063047, COSV53083210; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 18/48 reads (38%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK5 | c.3205C>T p.R1069C | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT deleterious (0.02); PolyPhen benign (0.325); catalogued as rs190638874; called by muse, mutect2, varscan2
- DOCK5 | c.3374T>C p.I1125T | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.607); catalogued as COSV52405681; called by muse, mutect2, varscan2
- DOCK9 | c.3932A>C p.K1311T (on ENST00000376460 / NM_001366676.2; = p.K1312T on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 95/205 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV59635082; called by muse, mutect2, varscan2
- DOT1L | c.2218G>A p.A740T | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.007); catalogued as rs1159247769, COSV67111165; called by muse, mutect2, varscan2
- DOT1L | c.3907del p.A1303Lfs*24 | Frame Shift Del (DEL) | VAF 7/18 reads (39%) | catalogued as COSV67113624; called by mutect2, pindel, varscan2
- DRP2 | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 36/38 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs766584694, COSV65810213; called by muse, mutect2, varscan2
- DSE | c.2293C>T p.R765W | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.189); catalogued as rs766035826, COSV59065387; called by muse, mutect2, varscan2
- DST | c.5491C>T p.R1831C | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1478923634; called by muse, mutect2, varscan2
- DSTYK | c.2353-1G>A p.X785_splice | Splice Site (SNP) | VAF 24/50 reads (48%) | catalogued as COSV65687204; called by muse, mutect2, varscan2
- DUSP2 | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs749713427, COSV56620056; called by muse, mutect2, varscan2
- EEFSEC | c.899G>A p.R300H | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748113210, COSV54628409; called by muse, mutect2, varscan2
- EFS | c.1640G>T p.G547V | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.815); catalogued as COSV52835556, COSV52836277; called by muse, mutect2, varscan2
- EGFLAM | c.1097del p.G366Afs*32 | Frame Shift Del (DEL) | VAF 21/70 reads (30%) | catalogued as rs773311790; called by mutect2, pindel, varscan2
- EGFR | c.3092G>A p.R1031Q | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.862); catalogued as rs570295933, COSV51817351; called by muse, varscan2
- EHD4 | c.1408G>A p.A470T | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs755305826, COSV55005736; called by muse, mutect2, varscan2
- EID3 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 78/174 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.17); catalogued as rs769543323, COSV61600007; called by muse, mutect2, varscan2
- EIF2AK3 | c.1930G>A p.A644T | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57549603; called by muse, mutect2, varscan2
- EIF3B | c.1085del p.G362Efs*28 | Frame Shift Del (DEL) | VAF 61/193 reads (32%) | catalogued as COSV62803535; called by mutect2, pindel, varscan2
- EIF5A2 | c.204del p.K68Nfs*24 | Frame Shift Del (DEL) | VAF 24/79 reads (30%) | catalogued as rs1366837041; called by mutect2, pindel, varscan2
- ELOA2 | c.1517G>A p.R506H | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.103); catalogued as COSV55302475; called by muse, mutect2, varscan2
- EMC2 | c.692G>C p.G231A | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1435977980, COSV55210145; called by muse, mutect2, varscan2
- EMC6 | c.140C>T p.T47I | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50265140; called by muse, mutect2, varscan2
- EMG1 | c.727dup p.V243Gfs*26 | Frame Shift Ins (INS) | VAF 32/87 reads (37%) | catalogued as rs782102656; called by mutect2, pindel, varscan2
- ENPP2 | c.153del p.W52Gfs*44 | Frame Shift Del (DEL) | VAF 23/107 reads (21%) | catalogued as COSV50016318; called by mutect2, pindel, varscan2
- EPB41L2 | c.1736C>A p.P579H | Missense Mutation (SNP) | VAF 56/148 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV61357030; called by muse, mutect2, varscan2
- EPHA2 | c.987del p.S330Pfs*63 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | catalogued as rs781025871; called by pindel, varscan2
- EPHB3 | c.2630G>A p.R877Q | Missense Mutation (SNP) | VAF 43/81 reads (53%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.54); catalogued as rs779302587, COSV57807354; called by muse, mutect2, varscan2
- EPS8L2 | c.1358G>A p.R453Q | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs371425662; called by muse, mutect2, varscan2
- ERG | c.698del p.G233Vfs*65 (on ENST00000398919 / NM_001243428.1; = p.G226Vfs*65 on NM_182918.4) | Frame Shift Del (DEL) | VAF 30/83 reads (36%) | catalogued as COSV55731356; called by mutect2, pindel, varscan2
- ESRRG | c.232G>T p.G78* | Nonsense Mutation (SNP) | VAF 45/78 reads (58%) | catalogued as COSV63158253, COSV63168875; called by muse, mutect2, varscan2
- ETV3 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); catalogued as rs1163203810, COSV58748797; called by mutect2, varscan2
- EVX2 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV57964109; called by muse, mutect2
- EWSR1 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 58/107 reads (54%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.318); catalogued as rs777722463, COSV53323835; called by muse, mutect2, varscan2
- EXOC7 | c.2116G>A p.V706M (on ENST00000335146 / NM_001145297.4; = p.V624M on NM_015219.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.225); catalogued as rs778698782, COSV58035070; called by muse, mutect2, varscan2
- FAM118A | c.286C>T p.R96W | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs755718603, COSV53416145; called by muse, mutect2, varscan2
- FAM135A | c.4151G>A p.G1384D (on ENST00000370479 / NM_001351599.1; = p.G1171D on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52054428; called by muse, mutect2, varscan2
- FAM151A | c.351del p.T118Lfs*43 | Frame Shift Del (DEL) | VAF 24/65 reads (37%) | catalogued as rs749953492; called by mutect2, pindel, varscan2
- FAM155A | c.815A>C p.D272A | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV65571024; called by muse, mutect2, varscan2
- FAM171A1 | c.829dup p.Q277Pfs*87 | Frame Shift Ins (INS) | VAF 42/135 reads (31%) | catalogued as rs1213864170; called by mutect2, pindel, varscan2
- FAM214A | c.2042del p.N681Mfs*5 | Frame Shift Del (DEL) | VAF 40/55 reads (73%) | catalogued as rs762546731, COSV55927849; called by mutect2, varscan2
- FAM71F1 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 60/108 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778124909, COSV59374182; called by muse, mutect2, varscan2
- FASN | c.1373C>T p.A458V | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.233); catalogued as rs143812680; called by muse, mutect2
- FAT2 | c.10376G>C p.G3459A | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs745811126, COSV55816485, COSV99941253; called by muse, mutect2, varscan2
- FAT3 | c.6010G>A p.V2004I | Missense Mutation (SNP) | VAF 59/161 reads (37%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.994); catalogued as COSV53137991; called by muse, mutect2, varscan2
- FAT3 | c.11723C>T p.S3908L | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs770021927, COSV53096009; called by muse, mutect2, varscan2
- FBL | c.673A>G p.M225V | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.301); catalogued as rs1206790347, COSV55683264; called by muse, mutect2, varscan2
- FBLL1 | c.946C>T p.R316W | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771705606, COSV57924128; called by muse, mutect2, varscan2
- FBLN1 | c.1982G>A p.R661H | Missense Mutation (SNP) | VAF 114/255 reads (45%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.557); catalogued as rs369461467; called by muse, mutect2, varscan2
- FBXL5 | c.2071G>A p.E691K | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs143196332; called by muse, mutect2, varscan2
- FCRLA | c.484G>A p.G162R (on ENST00000367959; = p.G139R on NM_032738.4) | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745591681, COSV52686786, COSV99376450; called by muse, mutect2, varscan2
- FGB | c.984A>C p.K328N | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV57418857; called by muse, mutect2, varscan2
- FGF10 | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs751081612, COSV52936485; called by muse, mutect2, varscan2
- FGF23 | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs748615286, COSV52975809; called by muse, mutect2, varscan2
- FGFR1 | c.748C>T p.R250W (on ENST00000447712 / NM_023110.3; = p.R248W on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/47 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as CM063987, COSV58331135; called by muse, mutect2, varscan2
- FGFR4 | c.1748C>T p.P583L | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs138800021, COSV52805681; called by muse, mutect2, varscan2
- FIP1L1 | c.1442G>A p.R481H | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.976); catalogued as COSV60997879; called by muse, mutect2, varscan2
- FLII | c.1573G>A p.A525T | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV58946092; called by muse, mutect2, varscan2
- FMN2 | c.1581del p.A528Rfs*140 | Frame Shift Del (DEL) | VAF 7/9 reads (78%) | catalogued as rs1237003165, COSV100147023, COSV60432328; called by mutect2, varscan2
- FOXJ1 | c.880C>T p.P294S | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs1271915008, COSV53946089, COSV53947173; called by muse, mutect2, varscan2
- FOXJ2 | c.884C>A p.P295Q | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV50820432; called by muse, mutect2, varscan2
- FOXO4 | c.1471A>G p.M491V | Missense Mutation (SNP) | VAF 33/39 reads (85%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs759518671, COSV58575695; called by muse, mutect2, varscan2
- FRAS1 | c.9217C>T p.Q3073* | Nonsense Mutation (SNP) | VAF 56/128 reads (44%) | catalogued as COSV53625191; called by muse, mutect2, varscan2
- FREM1 | c.4465C>T p.R1489W | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1029084142, COSV66526194; called by muse, mutect2, varscan2
- FREM1 | c.1570C>A p.L524I | Missense Mutation (SNP) | VAF 51/125 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV66526202; called by muse, mutect2, varscan2
- FSCN1 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV61018103; called by muse, mutect2, varscan2
- FSCN1 | c.728G>A p.G243D | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as rs1329021779; called by muse, mutect2, varscan2
- FSCN3 | c.365A>G p.D122G | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.294); catalogued as COSV50001420; called by muse, mutect2, varscan2
- FSIP1 | c.1537G>A p.V513I | Missense Mutation (SNP) | VAF 53/120 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as rs758206272, COSV63225603; called by muse, mutect2, varscan2
- FSTL5 | c.1530A>C p.K510N | Missense Mutation (SNP) | VAF 57/132 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.091); catalogued as COSV60186684; called by muse, mutect2, varscan2
- FYB2 | c.1153del p.M385* | Frame Shift Del (DEL) | VAF 11/45 reads (24%) | catalogued as rs762431846; called by mutect2, pindel, varscan2
- G6PD | c.746A>G p.Y249C | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63703645; called by muse, mutect2, varscan2
- GABRR3 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.466); catalogued as rs564538143, COSV72084092; called by muse, mutect2, varscan2
- GALC | c.454T>C p.S152P | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV54323643; called by muse, mutect2, varscan2
- GARRE1 | c.2461C>T p.R821C | Missense Mutation (SNP) | VAF 17/174 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1383043124, COSV55101148; called by muse, mutect2
- GAS7 | c.724C>T p.R242W (on ENST00000432992 / NM_201433.2; = p.R102W on NM_003644.3) | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1371273884, COSV60439446; called by muse, mutect2, varscan2
- GATD1 | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs371321156; called by muse, mutect2, varscan2
- GCLC | c.200G>T p.G67V (on ENST00000643939; = p.G71V on NM_001498.4) | Missense Mutation (SNP) | VAF 5/113 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.089); catalogued as COSV57596423; called by muse, mutect2
- GDF15 | c.724G>A p.G242S | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs887907177, COSV53251367; called by muse, mutect2, varscan2
- GDF5 | c.997G>A p.A333T | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs767571173, COSV65502152; called by muse, mutect2, varscan2
- GEM | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs769234376, COSV52596968; called by muse, mutect2, varscan2
- GFOD2 | c.638G>A p.G213D | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV52058778; called by muse, mutect2, varscan2
- GIGYF1 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 145/244 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as rs1440155839, COSV51940161; called by muse, mutect2, varscan2
- GINS1 | c.515del p.N172Ifs*14 | Frame Shift Del (DEL) | VAF 26/64 reads (41%) | catalogued as rs750227570; called by mutect2, varscan2
- GLG1 | c.1208T>C p.M403T | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as rs762159317, COSV52670010; called by muse, mutect2, varscan2
- GLI2 | c.1732G>A p.V578I (on ENST00000361492 / NM_001374353.1; = p.V595I on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/134 reads (38%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.722); catalogued as rs768557650, COSV58043749; called by muse, mutect2, varscan2
- GMPPA | c.457G>A p.G153S | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58007586; called by muse, mutect2, varscan2
- GOLGA3 | c.1103C>T p.A368V | Missense Mutation (SNP) | VAF 66/82 reads (80%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.925); catalogued as COSV52636078; called by muse, mutect2, varscan2
- GON4L | c.4108G>T p.E1370* | Nonsense Mutation (SNP) | VAF 75/182 reads (41%) | catalogued as COSV55197386; called by muse, mutect2, varscan2
- GPATCH2 | c.217C>T p.R73W | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375962510; called by muse, varscan2
- GPN1 | c.81G>T p.M27I | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53115774; called by muse, mutect2, varscan2
- GPR101 | c.757A>G p.K253E | Missense Mutation (SNP) | VAF 99/109 reads (91%) | SIFT tolerated (0.41); PolyPhen benign (0.225); catalogued as COSV53239482; called by muse, mutect2, varscan2
- GPR55 | c.496T>C p.Y166H | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.832); catalogued as COSV67408114; called by muse, mutect2, varscan2
- GPR61 | c.832C>T p.R278W | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.273); catalogued as rs746738584, COSV63984086; called by muse, mutect2, varscan2
- GRB10 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 61/99 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs754152902, COSV60006986; called by muse, mutect2, varscan2
- GRID1 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1351108306, COSV60012932; called by muse, mutect2, varscan2
- GRIK3 | c.1413G>T p.K471N | Missense Mutation (SNP) | VAF 55/166 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.047); catalogued as COSV66142462, COSV66144876; called by muse, mutect2, varscan2
- GRIK3 | c.707C>G p.T236S | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV66138054, COSV66142466; called by muse, mutect2, varscan2
- GRINA | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs145548367; called by muse, mutect2, varscan2
- GRM1 | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT tolerated (0.48); PolyPhen benign (0.031); catalogued as rs1018703074, COSV51148350, COSV51189456; called by muse, mutect2, varscan2
- GRM6 | c.727del p.V243Sfs*21 | Frame Shift Del (DEL) | VAF 40/136 reads (29%) | catalogued as rs281865186, CM1514172; ClinVar: not provided; called by mutect2, pindel, varscan2
- GTF2IRD2 | c.2149G>A p.G717R | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1554416367, COSV100736407; called by mutect2, varscan2
- GUCY2D | c.2434C>T p.R812W | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs894774212, COSV54696245; called by muse, mutect2, varscan2
- GUCY2D | c.3016G>A p.A1006T | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV54697195; called by muse, mutect2, varscan2
- H1-5 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs1455966427, COSV104403565, COSV58900625; called by muse, mutect2, varscan2
- H3C7 | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 59/139 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.316); catalogued as COSV55100324; called by muse, mutect2, varscan2
- HAPLN1 | c.902A>G p.Y301C | Missense Mutation (SNP) | VAF 61/184 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57149668; called by muse, mutect2, varscan2
- HARBI1 | c.826G>T p.G276* | Nonsense Mutation (SNP) | VAF 12/37 reads (32%) | catalogued as COSV58706421; called by muse, mutect2, varscan2
- HAUS3 | c.40del p.I14Lfs*27 | Frame Shift Del (DEL) | VAF 31/88 reads (35%) | catalogued as rs748396956; called by mutect2, varscan2
- HCN1 | c.809G>A p.R270Q | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57517608; called by muse, mutect2, varscan2
- HCN2 | c.1121T>C p.M374T | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV52116564; called by muse, mutect2, varscan2
- HCN4 | c.2527G>A p.A843T | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.028); catalogued as rs777023781, COSV56082985; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HEATR3 | c.722T>C p.V241A | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV53530282; called by muse, mutect2
- HECTD4 | c.5516C>A p.P1839Q | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66388045, COSV66394913; called by muse, mutect2, varscan2
- HELT | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0.168); catalogued as rs762115587, COSV58820160; called by muse, mutect2, varscan2
- HERC2 | c.8270C>T p.A2757V | Missense Mutation (SNP) | VAF 55/135 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs61755662; called by muse, mutect2, varscan2
- HERC2 | c.3166C>T p.R1056C | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55326230; called by muse, mutect2, varscan2
- HERC4 | c.2079T>A p.N693K (on ENST00000395198 / NM_022079.3; = p.N685K on NM_015601.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.477); catalogued as COSV53272884; called by muse, mutect2, varscan2
- HERC6 | c.1134A>C p.E378D | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV52031864; called by muse, mutect2, varscan2
- HHIP | c.37G>C p.A13P | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.266); catalogued as COSV56837258, COSV56841355; called by muse, mutect2, varscan2
- HNRNPLL | c.1079G>A p.G360E | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55368247; called by muse, mutect2, varscan2
- HNRNPM | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1242743579, COSV57693324; called by muse, mutect2, varscan2
- HPS5 | c.3269A>C p.E1090A (on ENST00000349215 / NM_181507.2; = p.E976A on NM_007216.4) | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV61687687; called by muse, mutect2
- HPSE | c.1393C>T p.R465W | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); catalogued as rs565705065, COSV60986699; called by muse, mutect2, varscan2
- HROB | c.597del p.A200Pfs*3 | Frame Shift Del (DEL) | VAF 57/155 reads (37%) | catalogued as COSV55369243; called by mutect2, pindel, varscan2
- HSD17B11 | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs148948833; called by muse, mutect2, varscan2
- HSD17B3 | c.108G>A p.W36* | Nonsense Mutation (SNP) | VAF 42/96 reads (44%) | catalogued as COSV64557638; called by muse, mutect2, varscan2
- HSP90AA1 | c.1159G>T p.G387W | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53489891; called by muse, mutect2, varscan2
- IFRD1 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs776628433, COSV50044565; called by muse, mutect2, varscan2
- IFT172 | c.1199A>G p.K400R | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT tolerated (0.29); PolyPhen benign (0.022); catalogued as COSV53135838; called by muse, mutect2, varscan2
- IGFN1 | c.3587G>T p.S1196I (on ENST00000295591 / NM_001367841.1; = p.S3653I on NM_001164586.2) | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as COSV55177078; called by muse, mutect2, varscan2
- IGHV3OR16-8 | c.140C>A p.T47N | Missense Mutation (SNP) | VAF 107/370 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.251); catalogued as rs892529943; called by muse, mutect2, varscan2
- IGSF22 | c.1601G>A p.C534Y | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.556); catalogued as COSV60036083; called by muse, mutect2, varscan2
- IKZF5 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 56/121 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs1253775182, COSV64397765; called by muse, mutect2, varscan2
- IL17RC | c.1581G>T p.W527C (on ENST00000295981 / NM_153461.4; = p.W441C on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 61/155 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55973975; called by muse, mutect2, varscan2
- IL6ST | c.1817T>C p.F606S | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.845); catalogued as COSV61141978; called by muse, mutect2, varscan2
- ILK | c.211del p.L71Cfs*26 | Frame Shift Del (DEL) | VAF 32/72 reads (44%) | catalogued as rs776120061, COSV54448886; ClinVar: uncertain significance; called by mutect2, varscan2
- IMPG2 | c.470A>G p.E157G | Missense Mutation (SNP) | VAF 56/143 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV51981361; called by muse, mutect2, varscan2
- INHBB | c.778G>A p.V260M | Missense Mutation (SNP) | VAF 52/101 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs770068466, COSV54677648; called by muse, mutect2, varscan2
- INSM2 | c.1484G>A p.R495H | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1476950229, COSV51888650; called by muse, mutect2, varscan2
- INTS3 | c.727C>T p.R243W | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs773242585, COSV59677965; called by muse, mutect2, varscan2
- INTS6L | c.359del p.L120* | Frame Shift Del (DEL) | VAF 13/39 reads (33%) | catalogued as rs782242788; ClinVar: uncertain significance; called by mutect2, varscan2
- INTU | c.395del p.N132Ifs*11 | Frame Shift Del (DEL) | VAF 46/121 reads (38%) | catalogued as rs771175764; called by mutect2, varscan2
- IP6K1 | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.943); catalogued as rs1000417584, COSV58664108; called by muse, mutect2, varscan2
- IPO13 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.056); catalogued as rs775594295, COSV64894306, COSV64894781; called by muse, mutect2, varscan2
- IQCF1 | c.238C>T p.R80W | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs931334848, COSV58823716; called by muse, mutect2, varscan2
- IQSEC1 | c.2789C>T p.S930L | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as rs761827844, COSV56225620; called by muse, mutect2, varscan2
- IRX1 | c.361G>A p.G121S | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57360666; called by muse, mutect2, varscan2
- IRX3 | c.725del p.G242Afs*18 | Frame Shift Del (DEL) | VAF 6/14 reads (43%) | catalogued as COSV61667883; called by mutect2, varscan2
- ISG20L2 | c.865del p.L289Sfs*15 | Frame Shift Del (DEL) | VAF 34/92 reads (37%) | catalogued as rs761558950, COSV57459436; called by mutect2, varscan2
- ITGA11 | c.2525C>T p.A842V | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.65); PolyPhen benign (0.136); catalogued as rs370831746; called by muse, mutect2, varscan2
- ITGA2B | c.1730A>G p.H577R | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV52233437; called by muse, mutect2, varscan2
- ITGAL | c.2474del p.P825Rfs*11 | Frame Shift Del (DEL) | VAF 75/224 reads (33%) | catalogued as COSV100776292; called by mutect2, pindel, varscan2
- ITGB4 | c.1634G>A p.R545H | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs1478257709, COSV52329059; called by muse, mutect2, varscan2
- ITPR1 | c.6676C>T p.R2226* (on ENST00000354582; = p.R2171* on NM_002222.7) | Nonsense Mutation (SNP) | VAF 5/18 reads (28%) | catalogued as COSV56990250; called by muse, mutect2, varscan2
- ITPRID1 | c.1030G>A p.A344T | Missense Mutation (SNP) | VAF 44/80 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.357); catalogued as COSV60077714; called by muse, mutect2, varscan2
- JADE3 | c.322C>T p.R108* | Nonsense Mutation (SNP) | VAF 28/30 reads (93%) | catalogued as COSV54468133; called by muse, mutect2, varscan2
- JRK | c.1158G>A p.W386* | Nonsense Mutation (SNP) | VAF 7/18 reads (39%) | catalogued as rs782111957, COSV70630065; called by muse, mutect2, varscan2
- KALRN | c.3603del p.G1202Afs*8 | Frame Shift Del (DEL) | VAF 37/118 reads (31%) | catalogued as rs771832826; called by mutect2, pindel, varscan2
- KAT6B | c.2467C>T p.P823S | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54750414; called by muse, mutect2, varscan2
- KAT8 | c.554G>A p.G185E | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54897649; called by muse, mutect2, varscan2
- KAT8 | c.708del p.E239Rfs*50 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | catalogued as rs773168027, COSV54895512; called by mutect2, pindel, varscan2
- KBTBD2 | c.331C>A p.L111I | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as COSV58363878; called by muse, mutect2
- KCNA4 | c.663del p.F221Lfs*21 | Frame Shift Del (DEL) | VAF 20/76 reads (26%) | catalogued as rs754892524; called by mutect2, varscan2
- KCNB2 | c.435del p.E146Nfs*3 | Frame Shift Del (DEL) | VAF 50/152 reads (33%) | catalogued as rs752059864; called by mutect2, varscan2
- KCNC4 | c.1726C>T p.R576C | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as rs754018819, COSV63926050; called by muse, mutect2, varscan2
- KCND1 | c.1720C>T p.R574C | Missense Mutation (SNP) | VAF 10/10 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.893); catalogued as rs973911149, COSV54414911; called by muse, mutect2, varscan2
- KCNG4 | c.1022C>T p.A341V | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs772160103, COSV57584742; called by muse, mutect2, varscan2
- KCNJ10 | c.305del p.P102Rfs*96 | Frame Shift Del (DEL) | VAF 32/91 reads (35%) | catalogued as rs765409185; called by mutect2, pindel, varscan2
- KCNQ2 | c.1118+6G>A | Splice Region (SNP) | VAF 43/111 reads (39%) | catalogued as rs528957010; called by muse, mutect2, varscan2
- KCTD18 | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV63344681; called by muse, mutect2
- KDM5A | c.3597del p.G1200Dfs*9 | Frame Shift Del (DEL) | VAF 54/128 reads (42%) | catalogued as rs771545848; called by mutect2, varscan2
- KHDC1 | c.254C>T p.P85L (on ENST00000370384 / NM_001251874.2; = p.P12L on NM_030568.5) | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs376978395; called by muse, mutect2, varscan2
- KIAA0930 | c.876del p.T293Pfs*27 (on ENST00000336156 / NM_001009880.2; = p.T298Pfs*27 on NM_015264.2) | Frame Shift Del (DEL) | VAF 14/51 reads (27%) | catalogued as rs1294718664; called by mutect2, pindel, varscan2
- KIAA1549L | c.4125dup p.T1376Hfs*62 (on ENST00000321505; = p.T1673Hfs*62 on NM_012194.3) | Frame Shift Ins (INS) | VAF 11/22 reads (50%) | catalogued as rs752808243; called by mutect2, pindel, varscan2
- KIF20A | c.1642G>A p.D548N | Missense Mutation (SNP) | VAF 61/149 reads (41%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV67510151; called by muse, mutect2, varscan2
- KIF21A | c.3703del p.I1235Ffs*7 (on ENST00000361418 / NM_001378440.1; = p.I1222Ffs*7 on NM_017641.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 15/39 reads (38%) | catalogued as rs761074592; called by mutect2, varscan2
- KIF23 | c.158A>G p.Q53R | Missense Mutation (SNP) | VAF 61/128 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.613); catalogued as COSV52981150; called by muse, mutect2, varscan2
- KIRREL3 | c.722C>T p.S241L | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.604); catalogued as rs372786849; called by muse, mutect2, varscan2
- KLHL14 | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.983); catalogued as COSV63833912; called by muse, mutect2, varscan2
- KLHL21 | c.1144G>A p.G382R | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768119966, COSV66553774; called by muse, mutect2, varscan2
- KLHL42 | c.1194del p.C399Vfs*44 | Frame Shift Del (DEL) | VAF 61/168 reads (36%) | catalogued as rs749194179; called by mutect2, pindel, varscan2
- KLK15 | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.11); catalogued as COSV56826514; called by muse, mutect2, varscan2
- KMT2A | c.2656C>T p.R886W | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1555036670, COSV63285364; called by muse, mutect2, varscan2
- KMT2C | c.14243C>T p.A4748V | Missense Mutation (SNP) | VAF 66/103 reads (64%) | SIFT tolerated (0.43); PolyPhen benign (0.232); catalogued as COSV51461499; called by muse, mutect2, varscan2
- KMT2C | c.7256C>A p.P2419H | Missense Mutation (SNP) | VAF 152/268 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); catalogued as rs1563275588, COSV51461519; called by muse, mutect2, varscan2
- KMT2C | c.4592C>T p.A1531V | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs587778491, COSV51461546; ClinVar: not provided; called by muse, mutect2, varscan2
- KMT2C | c.2597G>A p.R866Q | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.766); catalogued as rs1352121775, COSV51461562; called by muse, varscan2
- KMT2D | c.1792C>T p.R598C | Missense Mutation (SNP) | VAF 88/100 reads (88%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs778514296, COSV56459218; called by muse, mutect2, varscan2
- KMT5B | c.2648T>G p.L883R | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58567727; called by muse, mutect2, varscan2
- KPNA6 | c.1349G>A p.R450Q | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.074); catalogued as rs369321250; called by muse, mutect2, varscan2
- LAMA1 | c.1769C>T p.T590M | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs758586817, COSV67539769; called by muse, mutect2, varscan2
- LAMA5 | c.9053C>T p.P3018L | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as rs758378567, COSV53364320; called by muse, mutect2, varscan2
- LAMB4 | c.2332G>T p.G778* | Nonsense Mutation (SNP) | VAF 81/142 reads (57%) | catalogued as COSV52722597, COSV52723548; called by muse, mutect2, varscan2
- LARP7 | c.246dup p.L83Ifs*4 | Frame Shift Ins (INS) | VAF 22/71 reads (31%) | catalogued as rs1318486735; called by mutect2, pindel, varscan2
- LATS1 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 87/181 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.116); catalogued as COSV53594391; called by muse, mutect2, varscan2
- LDHD | c.469+1G>A p.X157_splice | Splice Site (SNP) | VAF 11/36 reads (31%) | catalogued as rs1567504157, COSV55581348; called by muse, mutect2, varscan2
- LENG1 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 56/134 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.059); catalogued as rs1382458369, COSV55365401; called by muse, mutect2, varscan2
- LHX6 | c.1020del p.V341Sfs*164 (on ENST00000373755 / NM_001242334.2; = p.V370Sfs*164 on NM_014368.5) | Frame Shift Del (DEL) | VAF 13/45 reads (29%) | catalogued as COSV100493338; called by mutect2, pindel, varscan2
- LIAS | c.107dup p.E37Gfs*16 | Frame Shift Ins (INS) | VAF 54/132 reads (41%) | catalogued as rs748571616; called by mutect2, varscan2
- LILRA6 | c.1360G>A p.A454T | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV54439913; called by muse, mutect2
- LIN54 | c.680T>C p.V227A | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV61202037; called by muse, mutect2, varscan2
- LINGO2 | c.1010A>G p.E337G | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58061475; called by muse, mutect2, varscan2
- LINGO3 | c.988C>T p.L330F | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68261545; called by muse, mutect2, varscan2
- LIPC | c.8C>T p.T3I | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.506); catalogued as COSV54424433; called by muse, mutect2, varscan2
- LMAN2 | c.937T>G p.F313V | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.039); catalogued as COSV57425098; called by muse, mutect2, varscan2
- LOXL2 | c.2069G>A p.R690H | Missense Mutation (SNP) | VAF 22/27 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752408071, COSV66692278; called by muse, mutect2, varscan2
- LPCAT3 | c.1307T>C p.M436T | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.233); catalogued as COSV54642620; called by muse, mutect2, varscan2
- LRP12 | c.1351del p.C451Afs*37 | Frame Shift Del (DEL) | VAF 45/214 reads (21%) | catalogued as rs35928649; called by pindel, varscan2
- LRP1B | c.10037C>T p.S3346F | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67245530; called by muse, mutect2, varscan2
- LRP2 | c.7656G>A p.M2552I | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV55561185; called by muse, mutect2
- LRRC3 | c.515G>A p.C172Y | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52399645; called by muse, mutect2, varscan2
- LRRC43 | c.1680del p.I561Sfs*10 | Frame Shift Del (DEL) | VAF 30/80 reads (38%) | catalogued as rs748039371; called by mutect2, pindel, varscan2
- LRRC66 | c.2161G>A p.A721T | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT tolerated (0.86); PolyPhen benign (0.036); catalogued as rs781398682, COSV58635018; called by muse, mutect2, varscan2
- LRRC66 | c.911G>A p.R304H | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58635029; called by muse, mutect2, varscan2
- LRRK1 | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.145); catalogued as COSV52617935; called by muse, mutect2, varscan2
- LRRN4 | c.1942C>T p.R648C | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs996185716, COSV66645951; called by muse, mutect2, varscan2
- LUZP2 | c.469del p.I157Sfs*5 | Frame Shift Del (DEL) | VAF 14/56 reads (25%) | catalogued as rs766421606; called by mutect2, varscan2
- LZTS3 | c.784G>A p.G262S | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs113680437, COSV61278401; called by muse, mutect2, varscan2
- MACF1 | c.10771G>A p.A3591T | Missense Mutation (SNP) | VAF 15/54 reads (28%) | catalogued as rs752155643, COSV57130152; called by muse, mutect2, varscan2
- MAGEA12 | c.497T>C p.V166A | Missense Mutation (SNP) | VAF 91/115 reads (79%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as COSV63295023, COSV63295577; called by muse, mutect2, varscan2
- MAGEB4 | c.62A>G p.Q21R | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as COSV64397393; called by muse, mutect2, varscan2
- MAN1C1 | c.1370del p.G457Afs*2 | Frame Shift Del (DEL) | VAF 17/58 reads (29%) | catalogued as COSV56043923; called by mutect2, pindel, varscan2
- MAP1B | c.2428G>A p.A810T | Missense Mutation (SNP) | VAF 51/104 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV57102070; called by muse, mutect2, varscan2
- MAP2 | c.2713C>T p.R905* | Nonsense Mutation (SNP) | VAF 21/61 reads (34%) | catalogued as COSV52283123; called by muse, mutect2, varscan2
- MAP3K12 | c.1688G>A p.R563H | Missense Mutation (SNP) | VAF 31/42 reads (74%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.41); catalogued as rs143743852; called by muse, mutect2, varscan2
- MAP4K1 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs769786941, COSV67710241; called by muse, mutect2, varscan2
- MAP9 | c.1700del p.K567Rfs*13 | Frame Shift Del (DEL) | VAF 15/50 reads (30%) | catalogued as rs1215313075; called by mutect2, pindel, varscan2
- MAPK1 | c.407G>A p.G136E | Missense Mutation (SNP) | VAF 61/154 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1569090943, COSV53187549; called by muse, mutect2, varscan2
- MAPKAP1 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1238730432, COSV56367419; called by muse, mutect2, varscan2
- MAST4 | c.2303C>T p.A768V (on ENST00000403625 / NM_001164664.2; = p.A579V on NM_015183.3) | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV55118515; called by muse, varscan2
- MATK | c.1153C>T p.R385W (on ENST00000310132 / NM_139355.3; = p.R386W on NM_002378.4) | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs1198216110, COSV59553614; called by muse, mutect2, varscan2
- MBD4 | c.939del p.E314Kfs*4 | Frame Shift Del (DEL) | VAF 51/140 reads (36%) | catalogued as rs558765093; called by mutect2, varscan2
- MBD6 | c.2080del p.Q694Sfs*5 | Frame Shift Del (DEL) | VAF 10/14 reads (71%) | catalogued as rs762648935; called by mutect2, varscan2
- MC3R | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 60/134 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1286756644, COSV54762849; called by muse, mutect2, varscan2
- MCEE | c.419del p.K140Rfs*6 | Frame Shift Del (DEL) | VAF 24/54 reads (44%) | catalogued as rs776473131; called by mutect2, varscan2
- MCHR1 | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as rs201684236, COSV50761974; called by muse, mutect2, varscan2
- MCM3AP | c.5039-2A>G p.X1680_splice | Splice Site (SNP) | VAF 20/33 reads (61%) | catalogued as COSV52441958; called by muse, mutect2, varscan2
- MCM3AP | c.2806C>T p.R936W | Missense Mutation (SNP) | VAF 72/191 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52441971; called by muse, mutect2, varscan2
- MCM8 | c.1226C>T p.S409L | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs771563950, COSV54515995; called by muse, mutect2, varscan2
- MED1 | c.2813G>A p.G938D | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.17); catalogued as COSV56126694; called by muse, mutect2, varscan2
- MED18 | c.505G>A p.V169M | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs749525888, COSV65790725; called by muse, mutect2, varscan2
- MEF2B | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs371035718; called by muse, mutect2, varscan2
- MFSD1 | c.1178T>C p.M393T | Missense Mutation (SNP) | VAF 32/366 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.14); catalogued as COSV51841913; called by muse, mutect2
- MFSD14B | c.490C>T p.R164* | Nonsense Mutation (SNP) | VAF 46/85 reads (54%) | catalogued as rs749609354, COSV64701255; called by muse, mutect2, varscan2
- MGAM | c.2176del p.L726Sfs*52 | Frame Shift Del (DEL) | VAF 158/336 reads (47%) | catalogued as COSV72075835; called by mutect2, pindel, varscan2
- MGAT1 | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 53/108 reads (49%) | PolyPhen benign (0.023); catalogued as rs1484605908, COSV57133938; called by muse, mutect2, varscan2
- MIB2 | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs367987171; called by muse, mutect2, varscan2
- MIB2 | c.1028C>T p.A343V | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.079); catalogued as rs368773238, COSV61755837; called by muse, mutect2
- MICAL3 | c.979C>T p.R327* | Nonsense Mutation (SNP) | VAF 23/60 reads (38%) | catalogued as COSV52900099; called by muse, mutect2, varscan2
- MINAR1 | c.2104del p.S702Afs*11 | Frame Shift Del (DEL) | VAF 99/135 reads (73%) | catalogued as rs748072217, COSV59581461; called by mutect2, varscan2
- MKI67 | c.7408G>T p.E2470* | Nonsense Mutation (SNP) | VAF 75/191 reads (39%) | catalogued as COSV64075376; called by muse, mutect2, varscan2
- MPDZ | c.5629A>G p.I1877V (on ENST00000319217 / NM_001330637.2; = p.I1848V on NM_003829.5) | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.852); catalogued as COSV59920225; called by muse, mutect2, varscan2
- MPP2 | c.1202G>A p.R401H (on ENST00000461854 / NM_001278372.2; = p.R377H on NM_005374.5) | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.224); catalogued as rs756893531, COSV52234871; called by muse, mutect2, varscan2
- MPP7 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 81/165 reads (49%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.459); catalogued as rs868850825, COSV61730067; called by muse, mutect2, varscan2
- MRC2 | c.4147G>A p.A1383T | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.207); catalogued as COSV57641673, COSV57645123; called by muse, mutect2, varscan2
- MROH1 | c.181T>C p.Y61H | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.109); catalogued as COSV58191061; called by muse, mutect2, varscan2
- MROH6 | c.817C>G p.L273V | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.701); catalogued as rs1226835037, COSV52786933; called by muse, mutect2, varscan2
- MRPL38 | c.1036C>T p.R346W | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.995); catalogued as rs745415254, COSV53932506; called by muse, mutect2, varscan2
- MRPL40 | c.134T>C p.M45T | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV54276803; called by muse, mutect2, varscan2
- MRPS15 | c.115G>T p.G39C | Missense Mutation (SNP) | VAF 65/209 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV58968889; called by muse, mutect2, varscan2
- MTARC1 | c.569G>A p.R190K | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.443); catalogued as rs879273251, COSV65055928; called by muse, mutect2, varscan2
- MTMR2 | c.1140G>T p.L380F | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.035); catalogued as COSV60580630; called by muse, mutect2
- MTNR1B | c.318G>A p.W106* | Nonsense Mutation (SNP) | VAF 77/190 reads (41%) | catalogued as COSV57067324, COSV99074445; called by muse, mutect2, varscan2
- MTOR | c.1431G>T p.Q477H | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.187); catalogued as COSV63874218; called by muse, mutect2, varscan2
- MTR | c.3259G>A p.A1087T | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as rs1431954928, COSV63965600, COSV99053626; called by muse, mutect2, varscan2
- MUC16 | c.30290A>G p.H10097R | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.012); catalogued as COSV67477746; called by muse, mutect2, varscan2
- MUC16 | c.19523C>A p.T6508N | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.136); catalogued as rs183160657, COSV67459067; called by muse, mutect2, varscan2
- MXRA8 | c.901del p.R301Gfs*107 | Frame Shift Del (DEL) | VAF 10/10 reads (100%) | catalogued as rs764857791; called by mutect2, varscan2
- MYBPC2 | c.2461G>A p.E821K | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.69); PolyPhen benign (0.045); catalogued as rs765717786, COSV63097301; called by muse, mutect2, varscan2
- MYEOV | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.369); catalogued as rs761264687, COSV58294681, COSV58294738; called by muse, mutect2, varscan2
- MYH14 | c.5227G>T p.A1743S | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0.206); catalogued as COSV51823493; called by muse, mutect2, varscan2
- MYO16 | c.2525del p.F842Sfs*17 | Frame Shift Del (DEL) | VAF 24/68 reads (35%) | catalogued as rs761471964; called by mutect2, varscan2
- MYO1D | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs1009367181, COSV59017463; called by muse, mutect2, varscan2
- MYO1F | c.1492G>A p.A498T | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as rs751748703, COSV57797048; called by muse, mutect2, varscan2
- MYO3A | c.3901A>G p.M1301V | Missense Mutation (SNP) | VAF 55/130 reads (42%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs745554914, COSV56337924; called by muse, mutect2, varscan2
- MYOT | c.107_110del p.K36Sfs*22 | Frame Shift Del (DEL) | VAF 62/139 reads (45%) | catalogued as rs398124238; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- MYRIP | c.1747C>T p.R583W | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); catalogued as rs771346658, COSV56873806; called by muse, mutect2, varscan2
- MZF1 | c.2150G>A p.R717H | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.595); catalogued as rs1432428963, COSV53042174; called by muse, mutect2, varscan2
- N4BP2 | c.2127del p.Y711Ifs*45 | Frame Shift Del (DEL) | VAF 54/145 reads (37%) | catalogued as COSV54704602; called by mutect2, pindel, varscan2
- NAA15 | c.1841del p.N614Mfs*22 | Frame Shift Del (DEL) | VAF 12/28 reads (43%) | catalogued as rs1283385686, COSV56718069; called by mutect2, varscan2
- NAA25 | c.1985dup p.S663Qfs*11 | Frame Shift Ins (INS) | VAF 83/225 reads (37%) | catalogued as rs1324340510; called by mutect2, varscan2
- NAGPA | c.492del p.L165Cfs*35 | Frame Shift Del (DEL) | VAF 11/22 reads (50%) | catalogued as rs761809784, COSV100392824; called by mutect2, pindel, varscan2
- NANOS3 | c.298C>T p.R100C (on ENST00000397555; = p.R119C on NM_001098622.2) | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as COSV59249268; called by muse, mutect2, varscan2
- NAT16 | c.247C>T p.R83C | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.077); catalogued as COSV55865043; called by muse, mutect2, varscan2
- NBAS | c.3247A>G p.T1083A | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.168); catalogued as rs781016222, COSV55728367; called by muse, mutect2
- NCAM2 | c.307C>G p.Q103E | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.056); catalogued as COSV53086658; called by muse, mutect2, varscan2
- NCK1 | c.269C>T p.A90V | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.012); catalogued as COSV56638480; called by muse, mutect2
- NCKAP1 | c.3346T>C p.Y1116H | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62941997; called by muse, mutect2, varscan2
- NDUFS7 | c.38G>A p.R13Q | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.031); catalogued as rs373814004; called by muse, mutect2, varscan2
- NECTIN2 | c.1148G>A p.R383Q | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs554767906, COSV52978425; called by muse, mutect2, varscan2
- NEDD9 | c.946G>A p.A316T | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.163); catalogued as rs1226283753, COSV65221469; called by muse, mutect2, varscan2
- NETO1 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 69/165 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.631); catalogued as rs1191425947, COSV55002344; called by muse, mutect2, varscan2
- NEURL4 | c.4529C>T p.A1510V | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.236); catalogued as COSV59747961; called by muse, mutect2, varscan2
- NFATC4 | c.493dup p.A165Gfs*23 | Frame Shift Ins (INS) | VAF 8/24 reads (33%) | catalogued as rs751744912; called by mutect2, varscan2
- NFIB | c.1036G>A p.G346R | Missense Mutation (SNP) | VAF 56/120 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.786); catalogued as COSV66627251; called by muse, mutect2, varscan2
- NFKBIB | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs567594250, COSV58004072; called by muse, mutect2, varscan2
- NIM1K | c.1139G>A p.R380H | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.133); catalogued as rs763182909, COSV58143269; called by muse, mutect2, varscan2
- NINJ1 | c.410C>T p.T137M | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs138077782; called by muse, mutect2, varscan2
- NIPBL | c.6365G>A p.S2122N | Missense Mutation (SNP) | VAF 62/150 reads (41%) | SIFT tolerated (0.5); PolyPhen benign (0.04); catalogued as COSV56957100; called by muse, mutect2, varscan2
- NKTR | c.1847del p.P616Lfs*21 | Frame Shift Del (DEL) | VAF 66/194 reads (34%) | catalogued as rs763440516; called by mutect2, varscan2
- NLRP1 | c.3535A>G p.T1179A | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.472); catalogued as COSV52570384; called by muse, mutect2, varscan2
- NLRP10 | c.496C>G p.P166A | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.928); catalogued as COSV60781088; called by muse, mutect2, varscan2
- NLRP11 | c.2195C>T p.A732V | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.36); catalogued as COSV64086149; called by muse, mutect2, varscan2
- NLRP7 | c.1540G>A p.D514N | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated (0.71); PolyPhen benign (0.061); catalogued as rs758296123, COSV60177190; called by muse, mutect2, varscan2
- NLRP9 | c.2498T>G p.L833R | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60465238; called by muse, mutect2, varscan2
- NOL8 | c.2194C>T p.R732W | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs758309678, COSV62636133; called by muse, mutect2, varscan2
- NOM1 | c.1541G>T p.R514M | Missense Mutation (SNP) | VAF 72/127 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51980873; called by muse, mutect2, varscan2
- NOS3 | c.1319del p.G440Afs*64 | Frame Shift Del (DEL) | VAF 35/130 reads (27%) | catalogued as rs749517498, COSV52496454; called by mutect2, pindel, varscan2
- NOX3 | c.706_707dup p.H237Cfs*37 | Frame Shift Ins (INS) | VAF 34/90 reads (38%) | catalogued as rs1444471765; called by mutect2, varscan2
- NPAP1 | c.2870C>T p.T957I | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.029); catalogued as COSV61508670; called by muse, mutect2, varscan2
- NPBWR1 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs778216443, COSV100488140, COSV58696846; called by muse, mutect2, varscan2
- NPHP3 | c.1304_1306del p.E435del | In Frame Del (DEL) | VAF 23/61 reads (38%) | catalogued as rs1456714047; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- NPR2 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs746138473, COSV61311923; called by muse, mutect2, varscan2
- NQO2 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.884); catalogued as rs1312838238, COSV57643173; called by muse, mutect2, varscan2
- NR2C2AP | c.29C>T p.T10I | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as COSV57394053, COSV57395400; called by muse, mutect2, varscan2
- NR4A1 | c.1562C>T p.P521L | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as rs991641788, COSV54484596; called by muse, mutect2
- NRN1 | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 20/27 reads (74%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.651); catalogued as COSV55205709; called by muse, mutect2, varscan2
- NRXN2 | c.3683T>C p.V1228A | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV55457158; called by muse, mutect2, varscan2
- NSRP1 | c.851G>T p.R284M | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.533); catalogued as COSV55934473; called by muse, mutect2, varscan2
- NT5C2 | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as rs769548902, COSV58417572; called by muse, mutect2, varscan2
- NUBP2 | c.223G>A p.G75S | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs542486228, COSV51906739; called by muse, mutect2, varscan2
- NUGGC | c.1892del p.N631Ifs*3 | Frame Shift Del (DEL) | VAF 67/88 reads (76%) | catalogued as rs755498396, COSV58439694; called by mutect2, varscan2
- NUMA1 | c.2255G>A p.R752Q | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771552205, COSV61187746; called by muse, mutect2, varscan2
- NUP214 | c.922A>G p.S308G | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs754369510, COSV63910977; called by muse, mutect2, varscan2
- NWD1 | c.3655G>A p.A1219T | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.234); catalogued as rs568003801, COSV60340525; called by muse, mutect2
- NXN | c.1030G>A p.A344T | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as rs866948738, COSV61097945; called by muse, mutect2, varscan2
- OAS3 | c.2896C>A p.L966I | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57447153; called by muse, mutect2, varscan2
- OCIAD1 | c.707T>C p.V236A | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT tolerated (0.42); PolyPhen benign (0.061); catalogued as rs1184821376; called by muse, mutect2
- OCIAD2 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 107/258 reads (41%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.997); catalogued as rs764161793, COSV56716998; called by muse, mutect2, varscan2
- OLFM2 | c.1282G>A p.A428T | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.647); catalogued as rs1223842673, COSV53431824; called by muse, mutect2, varscan2
- OMP | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.595); catalogued as rs369608660; called by muse, mutect2, varscan2
- ONECUT1 | c.994C>T p.R332C | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV59948856; called by muse, mutect2, varscan2
- OPTN | c.532T>G p.F178V | Missense Mutation (SNP) | VAF 52/112 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV53811757; called by muse, mutect2, varscan2
- OR10G7 | c.389G>T p.R130M | Missense Mutation (SNP) | VAF 112/134 reads (84%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV57867823; called by muse, mutect2, varscan2
- OR10Q1 | c.437C>T p.T146M | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.161); catalogued as COSV57470145; called by muse, mutect2, varscan2
- OR12D2 | c.891G>T p.K297N | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.467); catalogued as COSV65826804, COSV65828871; called by muse, mutect2
- OR2A2 | c.622G>A p.G208R | Missense Mutation (SNP) | VAF 67/240 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs374016349; called by muse, mutect2, varscan2
- OR2A25 | c.116T>C p.L39S | Missense Mutation (SNP) | VAF 74/135 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV68716876; called by muse, mutect2, varscan2
- OR2J3 | c.437T>C p.L146P | Missense Mutation (SNP) | VAF 126/334 reads (38%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.622); catalogued as COSV65849320; called by muse, mutect2, varscan2
- OR4L1 | c.461del p.L154Yfs*4 | Frame Shift Del (DEL) | VAF 16/165 reads (10%) | catalogued as rs759223784; called by mutect2, pindel, varscan2
- OR4Q3 | c.578T>C p.V193A | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV59179345; called by muse, mutect2
- OR51B2 | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 71/157 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as rs770237512, COSV60917092; called by muse, mutect2, varscan2
- OR52A5 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as rs1221037254, COSV56615866; called by muse, mutect2, varscan2
- OR52K1 | c.356C>A p.A119D | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56904099; called by muse, mutect2, varscan2
- OR5T3 | c.122dup p.L41Ffs*23 | Frame Shift Ins (INS) | VAF 32/93 reads (34%) | catalogued as rs1477723458; called by mutect2, pindel, varscan2
- OR6C70 | c.281G>A p.G94D | Missense Mutation (SNP) | VAF 70/81 reads (86%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.019); catalogued as rs867387220, COSV59245059; called by muse, mutect2, varscan2
- OR6K2 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as rs532035184, COSV62743770; called by muse, mutect2, varscan2
- OR8I2 | c.532del p.C178Vfs*7 | Frame Shift Del (DEL) | VAF 76/169 reads (45%) | catalogued as rs112181516, COSV56167552; called by mutect2, varscan2
- OSBPL1A | c.2378del p.N793Mfs*15 (on ENST00000319481 / NM_080597.4; = p.N280Mfs*15 on NM_018030.4) | Frame Shift Del (DEL) | VAF 36/104 reads (35%) | catalogued as rs751106039; called by mutect2, varscan2
- P3H1 | c.1670C>T p.T557M | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as rs762603538, COSV52535074; called by muse, mutect2, varscan2
- PACC1 | c.108A>C p.R36S | Missense Mutation (SNP) | VAF 113/297 reads (38%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); catalogued as COSV54788650; called by muse, mutect2, varscan2
- PAFAH1B1 | c.370G>A p.V124I | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.428); catalogued as COSV68210373; called by muse, mutect2, varscan2
- PAK2 | c.1436G>A p.R479Q | Missense Mutation (SNP) | VAF 55/113 reads (49%) | SIFT tolerated (0.37); PolyPhen benign (0.021); catalogued as rs759691640, COSV59082836; called by muse, mutect2, varscan2
- PARD6G | c.698C>T p.T233M | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772139500, COSV62061838; called by muse, mutect2, varscan2
- PARP14 | c.3965del p.N1322Ifs*26 | Frame Shift Del (DEL) | VAF 16/47 reads (34%) | catalogued as rs758945932; called by mutect2, varscan2
- PASD1 | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 48/57 reads (84%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as rs762258468, COSV64856169; called by muse, mutect2, varscan2
- PAX8 | c.355A>G p.N119D | Missense Mutation (SNP) | VAF 87/224 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.245); catalogued as COSV54510397; called by muse, mutect2, varscan2
- PCDH10 | c.1813G>A p.A605T | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52098240, COSV52106101; called by muse, mutect2, varscan2
- PCDH17 | c.1796G>A p.R599H | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1375857261, COSV64972185, COSV64973052, COSV64974497; called by muse, mutect2, varscan2
- PCDHAC2 | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV53843354; called by muse, mutect2, varscan2
- PCDHB4 | c.1122del p.G375Efs*6 | Frame Shift Del (DEL) | VAF 56/166 reads (34%) | catalogued as COSV52025519; called by mutect2, pindel, varscan2
- PCDHB8 | c.1619C>T p.P540L | Missense Mutation (SNP) | VAF 42/200 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs782031855, COSV50788123, COSV99177493; called by muse, mutect2, varscan2
- PCDHGA1 | c.1819C>T p.R607C | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.301); catalogued as rs775407166, COSV100965984; called by muse, mutect2, varscan2
- PCDHGA5 | c.2069C>T p.T690I | Missense Mutation (SNP) | VAF 162/434 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV53980467; called by muse, mutect2, varscan2
- PCDHGA7 | c.1384G>A p.A462T | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV53947493; called by muse, mutect2, varscan2
- PCDHGB5 | c.1792G>A p.A598T | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV53980506; called by muse, mutect2, varscan2
- PCLO | c.7325del p.K2442Sfs*2 | Frame Shift Del (DEL) | VAF 7/27 reads (26%) | catalogued as COSV61618667; called by mutect2, varscan2
- PCNX2 | c.2345C>T p.S782L | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT tolerated (0.85); PolyPhen benign (0.036); catalogued as rs761727858, COSV50825650; called by muse, mutect2, varscan2
- PCSK4 | c.703A>G p.T235A | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV52014090; called by muse, mutect2, varscan2
- PDE4DIP | c.1855C>T p.R619C | Missense Mutation (SNP) | VAF 52/104 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs367612221; called by muse, mutect2, varscan2
- PDE4DIP | c.2584A>G p.M862V | Missense Mutation (SNP) | VAF 91/229 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.118); catalogued as COSV57707890; called by muse, mutect2, varscan2
- PDE6B | c.2339C>T p.T780I | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as rs1225038079, COSV55328054; called by muse, mutect2, varscan2
- PEAK1 | c.889C>T p.R297* | Nonsense Mutation (SNP) | VAF 50/119 reads (42%) | catalogued as rs770000942, COSV56930966; called by muse, mutect2, varscan2
- PGAP6 | c.656C>T p.T219M | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs759772953, COSV51740630; called by muse, mutect2, varscan2
- PHACTR1 | c.466C>T p.R156* | Nonsense Mutation (SNP) | VAF 50/118 reads (42%) | catalogued as COSV60672515; called by muse, mutect2, varscan2
- PHF20 | c.2644C>T p.R882C | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs369820748; called by muse, mutect2, varscan2
- PHLPP2 | c.304C>T p.R102* | Nonsense Mutation (SNP) | VAF 30/77 reads (39%) | catalogued as rs1433313356, COSV62425468; called by muse, mutect2, varscan2
- PHOX2B | c.624C>A p.C208* | Nonsense Mutation (SNP) | VAF 15/48 reads (31%) | catalogued as COSV56930178, COSV56930406; called by muse, mutect2
- PHTF1 | c.1078C>T p.R360* | Nonsense Mutation (SNP) | VAF 18/51 reads (35%) | catalogued as rs779942328, COSV63367659; called by muse, mutect2, varscan2
- PI15 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 158/541 reads (29%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as COSV52642788; called by muse, mutect2, varscan2
- PIGV | c.856C>T p.R286W | Missense Mutation (SNP) | VAF 114/280 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs539783121, COSV50294386; called by muse, varscan2
- PIK3CD | c.1367C>T p.T456M | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as rs751570218, COSV63128196; called by muse, mutect2, varscan2
- PITPNM1 | c.3449G>A p.R1150Q | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.278); catalogued as rs559471785, COSV54161005; called by muse, mutect2, varscan2
- PKHD1 | c.10736T>C p.V3579A | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as COSV64394317; called by muse, mutect2
- PKHD1L1 | c.3115C>T p.Q1039* | Nonsense Mutation (SNP) | VAF 6/28 reads (21%) | catalogued as rs1388937729, COSV65746951; called by muse, mutect2, varscan2
- PKHD1L1 | c.8537G>A p.R2846H | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs375835470; called by muse, mutect2, varscan2
- PLCXD3 | c.548A>G p.Y183C | Missense Mutation (SNP) | VAF 48/152 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV60612193; called by muse, mutect2, varscan2
- PLD3 | c.1123C>T p.R375W | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as rs752779193, COSV52522413; called by muse, mutect2, varscan2
- PLEKHA5 | c.911T>C p.I304T | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV54705350; called by muse, mutect2, varscan2
- PLEKHB1 | c.390G>A p.P130= | Splice Region (SNP) | VAF 7/16 reads (44%) | catalogued as rs776921144, COSV57049888; called by muse, mutect2, varscan2
- PLEKHH3 | c.401G>A p.S134N | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV53190139; called by muse, mutect2, varscan2
- PLSCR1 | c.944C>T p.S315L | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV61013175; called by muse, mutect2, varscan2
- PLXNA3 | c.49dup p.A17Gfs*39 | Frame Shift Ins (INS) | VAF 24/32 reads (75%) | catalogued as rs782247826; called by mutect2, varscan2
- PLXNB1 | c.3143G>A p.R1048H | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs561091722, COSV56491711; called by muse, mutect2, varscan2
- PMP22 | c.163T>C p.S55P | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV56602760; called by muse, mutect2, varscan2
- PNPLA6 | c.3109C>T p.R1037W (on ENST00000414982 / NM_001166111.2; = p.R989W on NM_006702.5) | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV55380912; called by muse, mutect2, varscan2
- POLE3 | c.340del p.T114Qfs*32 | Frame Shift Del (DEL) | VAF 13/25 reads (52%) | catalogued as rs1340821595; called by mutect2, varscan2
- POLK | c.1552A>G p.N518D | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.092); catalogued as rs753805980, COSV54036944; called by muse, mutect2, varscan2
- POLL | c.1549C>T p.R517* | Nonsense Mutation (SNP) | VAF 43/112 reads (38%) | catalogued as rs371228435; called by muse, mutect2, varscan2
- POLM | c.290del p.P97Qfs*6 | Frame Shift Del (DEL) | VAF 88/176 reads (50%) | catalogued as rs745933237; called by mutect2, pindel, varscan2
- POLRMT | c.2467G>C p.A823P | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV52116574; called by muse, varscan2
- POM121C | c.3599C>T p.A1200V (on ENST00000607367; = p.A958V on NM_001099415.3) | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.388); catalogued as rs370125686; called by muse, mutect2, varscan2
- PON2 | c.195del p.F65Lfs*5 | Frame Shift Del (DEL) | VAF 61/132 reads (46%) | catalogued as rs1201102139; called by mutect2, pindel, varscan2
- POU3F4 | c.676G>A p.V226M | Missense Mutation (SNP) | VAF 32/39 reads (82%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV64539968; called by muse, mutect2, varscan2
- PPARD | c.773G>A p.R258Q | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.977); catalogued as rs750380211, COSV61100333; called by muse, mutect2, varscan2
- PPIG | c.2035G>A p.E679K | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); catalogued as rs1558904562, COSV53644262; called by muse, mutect2, varscan2
- PPP1R11 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1398067515, COSV54993812; called by muse, mutect2, varscan2
- PPP1R26 | c.2692del p.V898Sfs*56 | Frame Shift Del (DEL) | VAF 29/88 reads (33%) | catalogued as rs1365223299; called by mutect2, pindel, varscan2
- PPP1R3A | c.2927T>C p.V976A | Missense Mutation (SNP) | VAF 40/158 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV52886358; called by muse, mutect2, varscan2
- PPP2R3B | c.905C>T p.A302V | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs1398906777, COSV66813263; called by muse, mutect2, varscan2
- PPP3CB | c.161T>C p.V54A | Missense Mutation (SNP) | VAF 67/156 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV61153315; called by muse, mutect2, varscan2
- PPP5C | c.293G>A p.G98D | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50141089; called by muse, mutect2, varscan2
- PRAMEF14 | c.1190T>C p.L397P | Missense Mutation (SNP) | VAF 93/193 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58049960; called by muse, mutect2, varscan2
- PRDM15 | c.2660A>G p.K887R | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV54155527; called by muse, mutect2, varscan2
- PRKCI | c.826dup p.T276Nfs*16 | Frame Shift Ins (INS) | VAF 26/71 reads (37%) | catalogued as rs753143066; called by mutect2, varscan2
- PRKG2 | c.1832G>A p.C611Y | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52327374; called by muse, mutect2, varscan2
- PRKN | c.709A>G p.T237A | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV58241167; called by muse, mutect2, varscan2
- PRMT2 | c.1259C>G p.T420R | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.078); catalogued as COSV52456164; called by mutect2, varscan2
- PRND | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.013); catalogued as rs773175272, COSV59896474, COSV59896881; called by muse, mutect2, varscan2
- PRORP | c.257del p.L86* | Frame Shift Del (DEL) | VAF 26/68 reads (38%) | catalogued as rs760446387; called by mutect2, varscan2
- PRR11 | c.66del p.E23Kfs*9 | Frame Shift Del (DEL) | VAF 27/72 reads (38%) | catalogued as rs753236928; called by mutect2, varscan2
- PRR19 | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs751389491, COSV56626241; called by muse, mutect2, varscan2
- PRRC2A | c.1348C>T p.R450W | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs778782170, COSV63224817; called by muse, mutect2, varscan2
- PRSS45P | c.34C>T p.R12W | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); catalogued as rs778464593, COSV70577427; called by muse, mutect2, varscan2
- PSG7 | c.25T>C p.C9R | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.361); catalogued as COSV68445688; called by muse, mutect2, varscan2
- PSMB4 | c.781A>G p.S261G | Missense Mutation (SNP) | VAF 59/155 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.042); catalogued as COSV51852245; called by muse, mutect2, varscan2
- PSMD2 | c.806C>T p.A269V | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV59530534; called by muse, mutect2, varscan2
- PSMD5 | c.437T>C p.I146T | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.197); catalogued as rs754419425, COSV52961214; called by muse, mutect2, varscan2
- PSMF1 | c.788del p.P263Rfs*75 | Frame Shift Del (DEL) | VAF 35/90 reads (39%) | catalogued as COSV55674478; called by mutect2, pindel, varscan2
- PTGDR | c.281G>T p.R94L | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT tolerated (0.74); PolyPhen benign (0.009); catalogued as COSV60094352; called by muse, mutect2, varscan2
- PTGER2 | c.404A>G p.Y135C | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV55419385; called by muse, mutect2, varscan2
- PTPDC1 | c.2027dup p.L676Ffs*37 (on ENST00000375360 / NM_177995.3; = p.L728Ffs*37 on NM_152422.4) | Frame Shift Ins (INS) | VAF 31/70 reads (44%) | catalogued as rs751575326; called by mutect2, varscan2
- PTPRF | c.3524G>A p.R1175Q | Missense Mutation (SNP) | VAF 58/123 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.787); catalogued as rs200483026, COSV100741000, COSV63446499; called by muse, mutect2, varscan2
- PTPRJ | c.3068T>C p.V1023A | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV69253117; called by muse, mutect2
- PTPRS | c.5501G>A p.R1834Q | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771526918, COSV53626512; called by muse, mutect2
- PYGL | c.1510A>G p.I504V | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.508); catalogued as COSV53586973; called by muse, mutect2, varscan2
- QKI | c.401del p.K134Rfs*14 | Frame Shift Del (DEL) | VAF 52/70 reads (74%) | catalogued as rs755727862; called by mutect2, varscan2
- RAB30 | c.505C>T p.R169* | Nonsense Mutation (SNP) | VAF 43/123 reads (35%) | catalogued as rs918662721, COSV52627472; called by muse, mutect2, varscan2
- RAB3B | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 58/152 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1310110131, COSV65434679; called by muse, mutect2, varscan2
- RAB6C | c.466A>G p.R156G | Missense Mutation (SNP) | VAF 9/161 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV101308490; called by muse, mutect2
- RAD51AP1 | c.620A>G p.E207G (on ENST00000228843 / NM_001130862.2; = p.E190G on NM_006479.5) | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV57410894; called by muse, mutect2, varscan2
- RADIL | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 66/100 reads (66%) | SIFT tolerated (0.33); PolyPhen benign (0.078); catalogued as COSV68202167; called by muse, mutect2, varscan2
- RALGAPA2 | c.3260G>T p.R1087M | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.041); catalogued as COSV52502684; called by muse, mutect2, varscan2
- RANBP2 | c.5402G>A p.C1801Y | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); catalogued as rs1282516723, COSV51703710; called by muse, mutect2
- RAP1GAP2 | c.104C>T p.S35L | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.078); catalogued as rs754468943, COSV54581908; called by muse, mutect2, varscan2
- RAPGEF4 | c.451C>T p.R151* | Nonsense Mutation (SNP) | VAF 57/143 reads (40%) | catalogued as COSV51389254; called by muse, mutect2, varscan2
- RAPGEF5 | c.647del p.K216Rfs*22 (on ENST00000401957 / NM_001367602.2; = p.K519Rfs*22 on NM_012294.5) | Frame Shift Del (DEL) | VAF 24/88 reads (27%) | catalogued as rs770990761; called by mutect2, pindel, varscan2
- RASGRP2 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.47); PolyPhen benign (0.082); catalogued as COSV51220985; called by muse, mutect2, varscan2
- RBFOX2 | c.404C>T p.T135M (on ENST00000438146 / NM_001349995.2; = p.T65M on NM_014309.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 91/227 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as rs779107559, COSV53266107; called by muse, mutect2, varscan2
- RBM14 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as rs747929881, COSV59559699; called by muse, mutect2, varscan2
- RBM25 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs143840737, COSV56199852; called by muse, mutect2, varscan2
- RC3H2 | c.2738G>A p.R913H | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs773556826, COSV61801296; called by muse, mutect2, varscan2
- RCC1 | c.103G>A p.G35S | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV65779708; called by muse, mutect2, varscan2
- RECQL | c.125T>C p.L42P | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59085230; called by muse, mutect2, varscan2
- RELA | c.1459del p.H487Tfs*7 | Frame Shift Del (DEL) | VAF 21/79 reads (27%) | catalogued as COSV58014427; called by mutect2, pindel, varscan2
- RELN | c.10292G>A p.R3431H | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.984); catalogued as rs1442266027, COSV59003902; called by muse, mutect2, varscan2
- RERE | c.985A>G p.M329V | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.949); catalogued as COSV61945205; called by muse, mutect2, varscan2
- RFT1 | c.1355G>A p.R452H | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs372822382, COSV56249386; called by muse, mutect2, varscan2
- RHOBTB1 | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as rs141139124, COSV61957940; called by muse, mutect2, varscan2
- RINT1 | c.1571T>C p.M524T | Missense Mutation (SNP) | VAF 138/211 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV57559320; called by muse, mutect2, varscan2
- RIPOR2 | c.1348T>C p.S450P | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV52424765; called by muse, mutect2
- RMC1 | c.250A>G p.T84A | Missense Mutation (SNP) | VAF 90/201 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.089); catalogued as COSV52572831; called by muse, mutect2, varscan2
- RNF10 | c.2151G>T p.R717S | Missense Mutation (SNP) | VAF 89/100 reads (89%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV58046561; called by muse, mutect2, varscan2
- RNF17 | c.1639G>A p.A547T | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV55044500; called by muse, mutect2, varscan2
- RNF26 | c.1256C>T p.P419L | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779473222, COSV60990916; called by muse, mutect2, varscan2
- RNF41 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 34/47 reads (72%) | SIFT tolerated (0.32); PolyPhen benign (0.037); catalogued as rs1211466154, COSV61504663; called by muse, mutect2, varscan2
- ROBO1 | c.1963C>T p.Q655* | Nonsense Mutation (SNP) | VAF 16/37 reads (43%) | catalogued as COSV71396457; called by muse, mutect2, varscan2
- ROBO2 | c.1756C>T p.R586W | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs753772733, COSV59921975; called by muse, mutect2, varscan2
- ROCK2 | c.1426C>T p.R476C | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as rs1013023821, COSV55080135, COSV55081192; called by muse, mutect2, varscan2
- RPH3A | c.1355G>A p.R452Q (on ENST00000389385 / NM_001143854.2; = p.R448Q on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/31 reads (90%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs767497432, COSV66991337, COSV66991418; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 24/51 reads (47%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPRD1A | c.937T>C p.*313Rext*41 (on ENST00000357384; = p.*313Rext*18 on NM_018170.5) | Nonstop Mutation (SNP) | VAF 29/68 reads (43%) | catalogued as rs771583595, COSV61361674; called by muse, mutect2, varscan2
- RPRM | c.85T>C p.C29R | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57988937; called by muse, mutect2, varscan2
- RPSA | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1014126728; called by muse, mutect2, varscan2
- RRP8 | c.715C>T p.R239* | Nonsense Mutation (SNP) | VAF 15/31 reads (48%) | catalogued as rs745570524, COSV54450138; called by muse, mutect2, varscan2
- RTBDN | c.236G>A p.C79Y (on ENST00000393233 / NM_001270444.1; = p.C111Y on NM_031429.2) | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.595); catalogued as rs368091371; called by muse, mutect2, varscan2
- RTN1 | c.2149G>A p.A717T | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs372975011; called by muse, mutect2, varscan2
- RUBCNL | c.1122C>T p.V374= | Splice Region (SNP) | VAF 5/13 reads (38%) | catalogued as rs546085430, COSV59790659; called by muse, mutect2, varscan2
- RUSC2 | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as rs1291801701, COSV63429286; called by muse, mutect2, varscan2
- RYR2 | c.7234G>A p.G2412R | Missense Mutation (SNP) | VAF 67/145 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs550534270, COSV100772934, COSV63696306; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SACS | c.7102G>A p.A2368T | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV101207700, COSV66543147; called by muse, mutect2, varscan2
- SARDH | c.1631A>C p.D544A | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV64100211; called by muse, mutect2, varscan2
- SCN4A | c.1364A>G p.E455G | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV71127674; called by muse, mutect2, varscan2
- SDK2 | c.3884G>A p.R1295Q | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.197); catalogued as rs749455647, COSV66190487; called by muse, mutect2, varscan2
- SDK2 | c.1474G>A p.V492I | Missense Mutation (SNP) | VAF 66/182 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.483); catalogued as rs376227214; called by muse, mutect2, varscan2
- SEC13 | c.127C>T p.R43C (on ENST00000350697 / NM_183352.3; = p.R46C on NM_030673.4) | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.37); catalogued as rs757416423, COSV61602010; called by muse, mutect2, varscan2
- SEC23A | c.134T>C p.L45P | Missense Mutation (SNP) | VAF 50/106 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV56975908; called by muse, mutect2, varscan2
- SEC24C | c.1375del p.Q459Sfs*32 | Frame Shift Del (DEL) | VAF 68/194 reads (35%) | catalogued as rs764652839; called by mutect2, pindel, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 22/54 reads (41%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SEMA4B | c.2282G>A p.C761Y | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.062); catalogued as COSV60174448, COSV60175015; called by mutect2, varscan2
- SERPINA3 | c.142G>A p.G48R | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs763528043, COSV67586572; called by muse, mutect2, varscan2
- SERPINF2 | c.402G>T p.Q134H | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV60664859; called by muse, mutect2, varscan2
- SERTAD3 | c.90G>T p.Q30H | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV59325421; called by muse, mutect2, varscan2
- SETD2 | c.6190_6191dup p.D2064Efs*84 | Frame Shift Ins (INS) | VAF 88/236 reads (37%) | catalogued as rs749901643; called by mutect2, varscan2
- SEZ6 | c.915dup p.P306Afs*2 | Frame Shift Ins (INS) | VAF 10/32 reads (31%) | catalogued as rs766332422; called by mutect2, varscan2
- SFMBT2 | c.1172C>T p.A391V | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs750758773, COSV62805471; called by muse, mutect2, varscan2
- SH3TC2 | c.1922G>A p.R641H | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as rs199991156, CX097585, COSV60464990; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SHOC1 | c.4333del p.*1445Efs*45 | Frame Shift Del (DEL) | VAF 16/101 reads (16%) | catalogued as rs769088263; called by mutect2, pindel, varscan2
- SHTN1 | c.1607dup p.T537Nfs*3 | Frame Shift Ins (INS) | VAF 12/34 reads (35%) | catalogued as rs770680326; called by mutect2, varscan2
- SIGLEC1 | c.5006G>A p.R1669H | Missense Mutation (SNP) | VAF 51/124 reads (41%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs763965082, COSV52458978; called by muse, mutect2, varscan2
- SIN3B | c.3214G>A p.E1072K | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as rs138372644; called by muse, mutect2, varscan2
- SINHCAF | c.218del p.N73Tfs*6 | Frame Shift Del (DEL) | VAF 24/44 reads (55%) | catalogued as rs771414532; called by mutect2, varscan2
784 further variants in this file (416 protein-altering or splice-affecting, 338 silent, 30 other) are not listed here.
